Somatic mutation profile of tumor specimen TCGA-A5-A0G1-01A (aliquot TCGA-A5-A0G1-01A-11D-A122-09) from TCGA case TCGA-A5-A0G1, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Endometrium; FIGO stage: Stage IA; Tumor grade: G3; Age at diagnosis: 67.0 years (24,477 days).
Specimen TCGA-A5-A0G1-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 0693f83b-30bf-412d-a398-5684fcb0b997.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-A5-A0G1-10A (Blood Derived Normal), aliquot TCGA-A5-A0G1-10A-01D-A122-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/aefae589-242f-4f70-ac76-38c7a860f699

The open-access MAF lists 11,095 somatic variants for this specimen: 8,247 protein-altering or splice-affecting, 2,629 silent, 219 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 7,273, Silent 2,629, Nonsense Mutation 615, Splice Site 211, Splice Region 94, Intron 81, RNA 67, 3'UTR 31, Frame Shift Del 21, Frame Shift Ins 19, 5'Flank 14, 3'Flank 14.

Variants (750 of 11,095; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ARID1A | c.5965C>T p.R1989* | Nonsense Mutation (SNP) | VAF 41/191 reads (21%) | hotspot (GDC flag); catalogued as rs879255270, CM1311944, COSV61370535; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ARID1B | c.3970C>T p.R1324* | Nonsense Mutation (SNP) | VAF 23/122 reads (19%) | catalogued as rs773740590, CM1310769, COSV51676754; ClinVar: pathogenic; called by muse, mutect2, varscan2
- CASQ2 | c.97C>T p.R33* | Nonsense Mutation (SNP) | VAF 24/123 reads (20%) | catalogued as rs397507556, CM024341, COSV54773805; ClinVar: pathogenic / likely pathogenic; called by muse, varscan2
- CDCA7 | c.821G>A p.R274H (on ENST00000347703 / NM_145810.3; = p.R353H on NM_031942.5) | Missense Mutation (SNP) | VAF 26/141 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs370384522, CM157794; ClinVar: pathogenic; called by muse, mutect2, varscan2
- COL7A1 | c.6005G>A p.R2002H | Missense Mutation (SNP) | VAF 7/26 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs768326843, COSV60395911; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- CRYAB | c.166C>T p.R56W | Missense Mutation (SNP) | VAF 39/191 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs387907338, CM092933; ClinVar: pathogenic; called by muse, mutect2, varscan2
- CTCF | c.1129C>T p.R377C | Missense Mutation (SNP) | VAF 24/111 reads (22%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV50461516; called by muse, mutect2, varscan2
- DMD | c.3535G>T p.E1179* | Nonsense Mutation (SNP) | VAF 34/188 reads (18%) | catalogued as rs794727422; ClinVar: pathogenic; called by muse, mutect2
- ERBB2 | c.2264T>C p.L755S | Missense Mutation (SNP) | VAF 64/358 reads (18%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121913470, COSV54062780, COSV54064269; ClinVar: likely pathogenic; called by muse, varscan2
- FANCC | c.520C>T p.R174* | Nonsense Mutation (SNP) | VAF 27/132 reads (20%) | catalogued as rs781542763, CS982190, COSV56657190; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- FANCM | c.1879C>T p.R627* | Nonsense Mutation (SNP) | VAF 25/119 reads (21%) | catalogued as rs374626826; ClinVar: pathogenic; called by muse, mutect2, varscan2
- FBN1 | c.1585C>T p.R529* | Nonsense Mutation (SNP) | VAF 9/47 reads (19%) | catalogued as rs137854476, CM074166; ClinVar: pathogenic; called by muse, mutect2, varscan2
- FBXW7 | c.1972C>T p.R658* (on ENST00000281708 / NM_001349798.2; = p.R578* on NM_018315.5) | Nonsense Mutation (SNP) | VAF 38/189 reads (20%) | hotspot (GDC flag); catalogued as COSV55892162, COSV55908751; called by muse, varscan2
- FOXA1 | c.749C>T p.S250F | Missense Mutation (SNP) | VAF 11/60 reads (18%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51644535, COSV51645490, COSV99032088; called by muse, mutect2, varscan2
- KAT6A | c.3385C>T p.R1129* | Nonsense Mutation (SNP) | VAF 60/281 reads (21%) | catalogued as rs786200960, CM151785, COSV55908606; ClinVar: pathogenic; called by muse, mutect2, varscan2
- KCNQ2 | c.1679G>A p.R560Q (on ENST00000359125 / NM_172107.4; = p.R532Q on NM_004518.6) | Missense Mutation (SNP) | VAF 11/54 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1057517919, COSV60556829; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- KCTD7 | c.591C>T p.C197= (on ENST00000275532; = p.R211* on NM_153033.5) | Silent (SNP) | VAF 36/162 reads (22%) | catalogued as rs750811871; ClinVar: pathogenic; called by muse, mutect2, varscan2
- KIF1A | c.920G>A p.R307Q | Missense Mutation (SNP) | VAF 56/305 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1064793161, CM1514260; ClinVar: pathogenic / likely pathogenic; called by muse, varscan2
- KMT2B | c.5336G>A p.R1779Q | Missense Mutation (SNP) | VAF 15/69 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.823); catalogued as rs779863547; ClinVar: pathogenic; called by muse, mutect2, varscan2
- LCA5 | c.238C>T p.R80* | Nonsense Mutation (SNP) | VAF 9/42 reads (21%) | catalogued as rs781035395, CM155708, COSV63973312; ClinVar: pathogenic; called by muse, mutect2, varscan2
- MECP2 | c.502C>T p.R168* | Nonsense Mutation (SNP) | VAF 20/133 reads (15%) | catalogued as rs61748421, CM993353, COSV100318642; ClinVar: pathogenic; called by muse, mutect2, varscan2
- MSH6 | c.2836G>T p.E946* | Nonsense Mutation (SNP) | VAF 19/70 reads (27%) | catalogued as rs1558666905, COSV52274084; ClinVar: pathogenic; called by muse, mutect2, varscan2
- MSH6 | c.3964G>T p.E1322* | Nonsense Mutation (SNP) | VAF 14/85 reads (16%) | catalogued as rs1553333707, CM1412053, COSV52274101; ClinVar: pathogenic; called by muse, mutect2, varscan2
- NBEAL2 | c.2701C>T p.R901* | Nonsense Mutation (SNP) | VAF 10/73 reads (14%) | catalogued as rs387907112, CM116015; ClinVar: pathogenic; called by muse, mutect2, varscan2
- NR3C1 | c.1430G>A p.R477H | Missense Mutation (SNP) | VAF 46/249 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs104893913, CM014593, COSV51541690; ClinVar: pathogenic; called by muse, mutect2, varscan2
- NR3C2 | c.1951C>T p.R651* | Nonsense Mutation (SNP) | VAF 36/214 reads (17%) | catalogued as rs1131691921, CM127494, COSV60987868; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- NSD1 | c.5740C>T p.R1914C | Missense Mutation (SNP) | VAF 21/101 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs587784154, CM043038, COSV61777511; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- NSD1 | c.6349C>T p.R2117* | Nonsense Mutation (SNP) | VAF 31/138 reads (22%) | catalogued as rs587784190, CM056664, COSV100728579; ClinVar: pathogenic; called by muse, mutect2, varscan2
- PIGO | c.1959G>A p.W653* | Nonsense Mutation (SNP) | VAF 13/63 reads (21%) | catalogued as rs1391418639; ClinVar: pathogenic; called by muse, mutect2, varscan2
- PIK3R1 | c.1042C>T p.R348* (on ENST00000521381 / NM_181523.3; = p.R78* on NM_181504.4) | Nonsense Mutation (SNP) | VAF 73/370 reads (20%) | hotspot (GDC flag); catalogued as rs1057520690, COSV57123475; ClinVar: pathogenic; called by muse, mutect2, varscan2
- RICTOR | c.3302C>T p.S1101L | Missense Mutation (SNP) | VAF 31/168 reads (18%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as rs776074870, COSV57119127; called by muse, mutect2, varscan2
- RPGRIP1 | c.2935C>T p.Q979* | Nonsense Mutation (SNP) | VAF 22/115 reads (19%) | catalogued as rs1371805993; ClinVar: pathogenic; called by muse, mutect2, varscan2
- SLC26A4 | c.227C>T p.P76L | Missense Mutation (SNP) | VAF 22/543 reads (4%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as rs1345175795, CM074546; ClinVar: likely pathogenic; called by muse, mutect2
- STK11 | c.409C>T p.Q137* | Nonsense Mutation (SNP) | VAF 27/95 reads (28%) | catalogued as rs730881970, CM041079, COSV58822821; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TNNI3 | c.421C>T p.R141W | Missense Mutation (SNP) | VAF 21/98 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs730881071; ClinVar: likely pathogenic / uncertain significance; called by muse, mutect2, varscan2
- TRAPPC11 | c.1192C>T p.R398* | Nonsense Mutation (SNP) | VAF 34/244 reads (14%) | catalogued as rs140403642; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- TTN | c.64630C>T p.R21544* (on ENST00000591111; = p.R14120* on NM_003319.4) | Nonsense Mutation (SNP) | VAF 22/128 reads (17%) | catalogued as rs878854328, COSV60187591; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- UGT1A1 | c.1006C>T p.R336W | Missense Mutation (SNP) | VAF 47/253 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs139607673, CM983520; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ZNF462 | c.3898C>T p.R1300* | Nonsense Mutation (SNP) | VAF 25/123 reads (20%) | catalogued as rs1176008720; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- A1BG | c.160G>A p.E54K | Missense Mutation (SNP) | VAF 20/112 reads (18%) | SIFT tolerated (0.86); PolyPhen benign (0.021); catalogued as rs1338064132; called by muse, varscan2
- AAAS | c.896G>T p.G299V | Missense Mutation (SNP) | VAF 13/86 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52933086; called by muse, mutect2, varscan2
- AADACL2 | c.950C>A p.A317E | Missense Mutation (SNP) | VAF 32/150 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as rs746482766, COSV100735845; called by muse, varscan2
- AADACL4 | c.772G>A p.A258T | Missense Mutation (SNP) | VAF 20/126 reads (16%) | SIFT tolerated (0.52); PolyPhen benign (0.017); catalogued as rs1557553979, COSV100879408; called by muse, mutect2, varscan2
- AARS2 | c.2444C>T p.A815V | Missense Mutation (SNP) | VAF 16/87 reads (18%) | SIFT tolerated (0.45); PolyPhen benign (0); catalogued as rs138828031; called by muse, mutect2, varscan2
- AARS2 | c.298C>T p.R100* | Nonsense Mutation (SNP) | VAF 32/164 reads (20%) | catalogued as rs771082902, COSV99771395; called by muse, mutect2, varscan2
- ABCA12 | c.4651G>A p.E1551K (on ENST00000272895 / NM_173076.3; = p.E1233K on NM_015657.3) | Missense Mutation (SNP) | VAF 6/41 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.543); catalogued as rs1463500622; called by muse, varscan2
- ABCA12 | c.1147A>C p.N383H (on ENST00000272895 / NM_173076.3; = p.N65H on NM_015657.3) | Missense Mutation (SNP) | VAF 48/248 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.007); catalogued as rs1407524828; called by muse, mutect2, varscan2
- ABCA13 | c.2528C>T p.S843L | Missense Mutation (SNP) | VAF 20/90 reads (22%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.888); catalogued as COSV70026970; called by muse, mutect2, varscan2
- ABCA3 | c.5051C>T p.S1684L | Missense Mutation (SNP) | VAF 12/81 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.825); catalogued as rs766677326, COSV100068830; called by muse, mutect2, varscan2
- ABCA7 | c.4612G>A p.V1538I | Missense Mutation (SNP) | VAF 48/248 reads (19%) | SIFT tolerated (0.09); PolyPhen benign (0.072); catalogued as rs140816246; called by muse, varscan2
- ABCB1 | c.2689G>A p.A897T | Missense Mutation (SNP) | VAF 14/78 reads (18%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.614); catalogued as rs147487745; called by muse, varscan2
- ABCB7 | c.1775T>G p.L592R (on ENST00000373394 / NM_001271696.3; = p.L593R on NM_004299.6) | Missense Mutation (SNP) | VAF 15/63 reads (24%) | SIFT tolerated (0.38); PolyPhen benign (0.043); catalogued as rs774449299; called by muse, mutect2, varscan2
- ABCB7 | c.85C>T p.R29W | Missense Mutation (SNP) | VAF 14/45 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.639); catalogued as rs1012910077; called by muse, mutect2, varscan2
- ABCB9 | c.1339G>A p.A447T | Missense Mutation (SNP) | VAF 20/166 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.083); catalogued as rs144010660; called by muse, varscan2
- ABCC1 | c.3368G>A p.G1123D | Missense Mutation (SNP) | VAF 9/68 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs770719562; called by muse, mutect2, varscan2
- ABCC12 | c.103G>A p.V35M | Missense Mutation (SNP) | VAF 28/128 reads (22%) | SIFT tolerated (0.13); PolyPhen benign (0.027); catalogued as COSV60917089; called by muse, mutect2, varscan2
- ABCC4 | c.3608C>T p.A1203V | Missense Mutation (SNP) | VAF 18/93 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs373949612; called by muse, mutect2, varscan2
- ABCC9 | c.4517G>A p.R1506H | Missense Mutation (SNP) | VAF 32/178 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs777661095, COSV53982913; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ABCC9 | c.2155C>T p.L719F | Missense Mutation (SNP) | VAF 21/146 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs141925577; called by muse, mutect2, varscan2
- ABCC9 | c.268G>A p.G90S | Missense Mutation (SNP) | VAF 55/251 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53980867; called by muse, varscan2
- ABCF2-H2BE1 | c.1866C>T p.N622= | Splice Region (SNP) | VAF 17/82 reads (21%) | catalogued as rs142050158, COSV55182382; called by muse, mutect2, varscan2
- ABHD13 | c.968C>T p.S323F | Missense Mutation (SNP) | VAF 10/68 reads (15%) | SIFT tolerated (0.09); PolyPhen benign (0.332); catalogued as rs1184086992, COSV65535472; called by muse, varscan2
- ABHD6 | c.203C>A p.P68H | Missense Mutation (SNP) | VAF 18/67 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as COSV55908762; called by muse, mutect2, varscan2
- ABHD8 | c.718C>T p.R240C | Missense Mutation (SNP) | VAF 14/88 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.685); catalogued as rs1430932500; called by muse, mutect2, varscan2
- ABL2 | c.281G>T p.R94M (on ENST00000502732 / NM_007314.4; = p.R79M on NM_005158.5) | Missense Mutation (SNP) | VAF 34/193 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100772605; called by muse, mutect2, varscan2
- ABTB2 | c.2005C>T p.L669F | Missense Mutation (SNP) | VAF 4/13 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1386927706; called by muse, mutect2, varscan2
- AC008397.2 | c.716G>A p.R239Q | Missense Mutation (SNP) | VAF 20/81 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.9); catalogued as rs1042552963; called by muse, mutect2, varscan2
- AC097636.1 | c.206C>T p.T69M | Missense Mutation (SNP) | VAF 10/52 reads (19%) | SIFT tolerated (0.12); PolyPhen benign (0.058); catalogued as rs201908745; called by muse, mutect2, varscan2
- AC132217.2 | c.142G>A p.G48S | Missense Mutation (SNP) | VAF 14/53 reads (26%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.001); catalogued as rs147404873, COSV56098752; called by muse, mutect2, varscan2
- ACACB | c.2192G>T p.R731M | Missense Mutation (SNP) | VAF 25/161 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs761608576; called by muse, mutect2
- ACAD11 | c.1880G>A p.R627H | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.244); catalogued as rs544486722, COSV53894996; called by mutect2, varscan2
- ACADM | c.760G>T p.D254Y | Missense Mutation (SNP) | VAF 60/395 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs1431463788, COSV57714280; called by muse, mutect2, varscan2
- ACADVL | c.1076C>T p.A359V | Missense Mutation (SNP) | VAF 34/152 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.227); catalogued as rs539029862, CM1512185; ClinVar: uncertain significance; called by muse, mutect2
- ACBD3 | c.955A>G p.T319A | Missense Mutation (SNP) | VAF 29/142 reads (20%) | SIFT tolerated (0.74); PolyPhen benign (0); catalogued as rs776590252; called by muse, varscan2
- ACD | c.814G>A p.V272M (on ENST00000620338; = p.V183M on NM_022914.3) | Missense Mutation (SNP) | VAF 10/79 reads (13%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.995); catalogued as rs780989111, CM150699, COSV54667412; called by mutect2, varscan2
- ACER1 | c.596G>T p.R199M | Missense Mutation (SNP) | VAF 15/70 reads (21%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.754); catalogued as COSV56834648; called by muse, varscan2
- ACER2 | c.235G>A p.V79I | Missense Mutation (SNP) | VAF 108/564 reads (19%) | SIFT tolerated (0.14); PolyPhen benign (0.269); catalogued as rs770384271, COSV61820954; called by muse, mutect2, varscan2
- ACER2 | c.490G>A p.A164T | Missense Mutation (SNP) | VAF 81/396 reads (20%) | SIFT tolerated (0.62); PolyPhen benign (0.003); catalogued as rs1272815814; called by muse, mutect2, varscan2
- ACIN1 | c.3566C>T p.A1189V | Missense Mutation (SNP) | VAF 100/512 reads (20%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.018); catalogued as rs1327766019; called by muse, mutect2, varscan2
- ACKR3 | c.271C>A p.L91M | Missense Mutation (SNP) | VAF 30/153 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs145205829, COSV99799858; called by muse, mutect2, varscan2
- ACOT1 | c.766G>A p.G256S | Missense Mutation (SNP) | VAF 35/150 reads (23%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.893); catalogued as rs757997047; called by muse, mutect2, varscan2
- ACOT2 | c.1028G>A p.R343H | Missense Mutation (SNP) | VAF 38/142 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as rs556081405, COSV53150563; called by muse, varscan2
- ACOT8 | c.521C>T p.A174V | Missense Mutation (SNP) | VAF 18/122 reads (15%) | SIFT tolerated (0.23); PolyPhen benign (0.054); catalogued as rs536673262, COSV54170564; called by muse, mutect2, varscan2
- ACOX2 | c.226C>T p.R76C | Missense Mutation (SNP) | VAF 21/104 reads (20%) | SIFT deleterious (0.04); PolyPhen benign (0.033); catalogued as rs369658583; called by muse, mutect2, varscan2
- ACSF3 | c.1294G>A p.V432M | Missense Mutation (SNP) | VAF 21/157 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); catalogued as rs763231512; called by muse, mutect2, varscan2
- ACSL4 | c.1975G>A p.A659T (on ENST00000340800 / NM_022977.2; = p.A618T on NM_004458.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 60/362 reads (17%) | SIFT tolerated (0.25); PolyPhen benign (0); catalogued as rs145872865; called by muse, mutect2, varscan2
- ACSL5 | c.1615G>A p.D539N (on ENST00000354273; = p.D595N on NM_016234.3) | Missense Mutation (SNP) | VAF 45/230 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs749931911, COSV61130657; called by muse, mutect2, varscan2
- ACSM1 | c.655G>A p.D219N | Missense Mutation (SNP) | VAF 11/52 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.971); catalogued as COSV54640781; called by muse, mutect2, varscan2
- ACTL9 | c.671C>T p.A224V | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.778); catalogued as rs1555753378, COSV61004991; called by muse, mutect2
- ACTN2 | c.1107G>A p.S369= | Splice Region (SNP) | VAF 14/70 reads (20%) | catalogued as rs369218950, COSV63977333; ClinVar: likely benign / uncertain significance; called by muse, mutect2, varscan2
- ACTN2 | c.1369C>T p.R457C | Missense Mutation (SNP) | VAF 5/37 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs769126818, COSV63974508; ClinVar: uncertain significance; called by mutect2, varscan2
- ACTN3 | c.220C>T p.R74C | Missense Mutation (SNP) | VAF 38/177 reads (21%) | SIFT tolerated (0.05); PolyPhen benign (0.307); catalogued as rs780052561; called by muse, mutect2, varscan2
- ACTN4 | c.1003T>G p.F335V | Missense Mutation (SNP) | VAF 22/110 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.862); catalogued as COSV53144260; called by muse, mutect2, varscan2
- ACTR3 | c.709G>T p.D237Y | Missense Mutation (SNP) | VAF 70/460 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV99603938; called by muse, mutect2, varscan2
- ACTRT1 | c.730C>T p.P244S | Missense Mutation (SNP) | VAF 5/37 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100947534, COSV64419565; called by muse, mutect2, varscan2
- ADA | c.247G>A p.A83T | Missense Mutation (SNP) | VAF 20/136 reads (15%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.818); catalogued as rs776103734, COSV65741032; called by muse, mutect2, varscan2
- ADA2 | c.1448G>A p.S483N (on ENST00000262607; = p.S242N on NM_177405.3) | Missense Mutation (SNP) | VAF 37/218 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs762701854; called by muse, mutect2, varscan2
- ADAM11 | c.439G>A p.A147T | Missense Mutation (SNP) | VAF 11/42 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.975); catalogued as rs760315607; called by muse, mutect2, varscan2
- ADAM17 | c.2140G>A p.E714K | Missense Mutation (SNP) | VAF 29/189 reads (15%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.897); catalogued as rs369159078; called by muse, mutect2, varscan2
- ADAM17 | c.989C>A p.S330Y | Missense Mutation (SNP) | VAF 15/77 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV100176028; called by muse, mutect2, varscan2
- ADAM20 | c.1280G>A p.R427Q | Missense Mutation (SNP) | VAF 14/75 reads (19%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs769342676; called by muse, mutect2, varscan2
- ADAM20 | c.530A>G p.E177G | Missense Mutation (SNP) | VAF 9/52 reads (17%) | SIFT deleterious (0.03); PolyPhen benign (0.009); catalogued as rs980720425, COSV56456591; called by muse, mutect2, varscan2
- ADAM22 | c.682C>T p.R228C | Missense Mutation (SNP) | VAF 22/136 reads (16%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.453); catalogued as rs535039786, COSV55969346; called by muse, mutect2, varscan2
- ADAMTS12 | c.3884C>T p.T1295I | Missense Mutation (SNP) | VAF 17/105 reads (16%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as COSV61281905; called by muse, mutect2, varscan2
- ADAMTS14 | c.2939G>A p.C980Y | Missense Mutation (SNP) | VAF 5/22 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1398832286; called by muse, mutect2, varscan2
- ADAMTS16 | c.1982G>A p.R661K | Missense Mutation (SNP) | VAF 12/61 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.679); catalogued as COSV56977608; called by muse, mutect2, varscan2
- ADAMTS16 | c.2341G>A p.V781I | Missense Mutation (SNP) | VAF 30/160 reads (19%) | SIFT tolerated (0.78); PolyPhen benign (0.007); catalogued as rs1206527862, COSV56982120; called by muse, mutect2, varscan2
- ADAMTS3 | c.3395G>T p.R1132M | Missense Mutation (SNP) | VAF 13/97 reads (13%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.169); catalogued as COSV99712299; called by muse, mutect2, varscan2
- ADAMTS5 | c.1852C>T p.L618F | Missense Mutation (SNP) | VAF 10/61 reads (16%) | SIFT tolerated (0.06); PolyPhen benign (0.224); catalogued as rs1348244216; called by muse, mutect2, varscan2
- ADAMTS7 | c.2813G>A p.R938H | Missense Mutation (SNP) | VAF 29/149 reads (19%) | SIFT tolerated (0.2); PolyPhen benign (0.003); catalogued as rs543802541, COSV66307450; called by muse, mutect2, varscan2
- ADAMTSL1 | c.76G>A p.A26T | Missense Mutation (SNP) | VAF 9/43 reads (21%) | SIFT tolerated (0.72); PolyPhen benign (0.003); catalogued as rs866189730, COSV52825642; called by muse, mutect2, varscan2
- ADAMTSL1 | c.2464G>A p.G822S | Missense Mutation (SNP) | VAF 43/256 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.889); catalogued as rs751667336, COSV65896701; called by muse, mutect2, varscan2
- ADAMTSL1 | c.5261G>A p.R1754H | Missense Mutation (SNP) | VAF 21/132 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs41268987; called by muse, mutect2, varscan2
- ADAMTSL2 | c.476G>A p.R159Q | Missense Mutation (SNP) | VAF 9/52 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs759233725; called by mutect2, varscan2
- ADAMTSL5 | c.322G>A p.G108S | Missense Mutation (SNP) | VAF 27/91 reads (30%) | SIFT tolerated (0.09); PolyPhen benign (0.116); catalogued as COSV100389248; called by muse, mutect2, varscan2
- ADCY1 | c.2494G>A p.D832N | Missense Mutation (SNP) | VAF 30/168 reads (18%) | SIFT tolerated (0.19); PolyPhen benign (0.208); catalogued as COSV99811462; called by muse, mutect2, varscan2
- ADCY10 | c.635C>T p.A212V | Missense Mutation (SNP) | VAF 22/126 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.289); catalogued as rs756467174; called by muse, mutect2, varscan2
- ADCY2 | c.467G>A p.R156Q | Missense Mutation (SNP) | VAF 13/76 reads (17%) | SIFT tolerated (0.27); PolyPhen benign (0.006); catalogued as rs138436408; called by muse, mutect2, varscan2
- ADCY3 | c.2638C>T p.R880C | Missense Mutation (SNP) | VAF 22/137 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.836); catalogued as rs369517755; called by muse, mutect2, varscan2
- ADCY4 | c.1108C>A p.H370N | Missense Mutation (SNP) | VAF 15/87 reads (17%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV60255897; called by muse, mutect2, varscan2
- ADCY5 | c.1087G>A p.A363T | Missense Mutation (SNP) | VAF 3/18 reads (17%) | SIFT tolerated (0.32); PolyPhen benign (0.028); catalogued as COSV71901477; called by muse, mutect2
- ADCY9 | c.2594G>A p.R865H | Missense Mutation (SNP) | VAF 16/111 reads (14%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.997); catalogued as rs770270080; called by muse, mutect2, varscan2
- ADGRA3 | c.283G>A p.E95K | Missense Mutation (SNP) | VAF 33/240 reads (14%) | SIFT tolerated (0.84); PolyPhen benign (0.183); catalogued as rs921364290, COSV100530299; called by muse, mutect2, varscan2
- ADGRB2 | c.914C>T p.A305V | Missense Mutation (SNP) | VAF 20/88 reads (23%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.787); catalogued as rs781471521, COSV57076022; called by muse, mutect2, varscan2
- ADGRB3 | c.2092A>C p.M698L | Missense Mutation (SNP) | VAF 57/270 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.023); catalogued as COSV101000409; called by muse, mutect2, varscan2
- ADGRB3 | c.2402C>T p.S801L | Missense Mutation (SNP) | VAF 29/146 reads (20%) | SIFT tolerated (0.12); PolyPhen benign (0.102); catalogued as rs747907463, COSV101000565, COSV65385017; called by muse, mutect2, varscan2
- ADGRB3 | c.4354C>T p.R1452W | Missense Mutation (SNP) | VAF 17/80 reads (21%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.928); catalogued as rs1197657726, COSV53232994; called by muse, mutect2, varscan2
- ADGRG3 | c.523G>A p.G175S | Missense Mutation (SNP) | VAF 12/83 reads (14%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs761516884; called by muse, mutect2, varscan2
- ADGRG4 | c.526C>T p.R176C | Missense Mutation (SNP) | VAF 16/126 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.448); catalogued as rs896110034, COSV54951846, COSV54957798; called by muse, varscan2
- ADGRG4 | c.527G>A p.R176H | Missense Mutation (SNP) | VAF 22/122 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as rs749849930; called by muse, mutect2, varscan2
- ADGRG4 | c.6854C>A p.S2285Y | Missense Mutation (SNP) | VAF 34/182 reads (19%) | SIFT deleterious (0.03); PolyPhen benign (0.178); catalogued as COSV99795602; called by muse, mutect2, varscan2
- ADGRG4 | c.7295C>T p.T2432M | Missense Mutation (SNP) | VAF 20/114 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs143014685; called by muse, mutect2, varscan2
- ADGRV1 | c.10051C>A p.L3351M | Missense Mutation (SNP) | VAF 17/78 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.896); catalogued as rs1445890457; called by muse, mutect2, varscan2
- ADORA1 | c.3G>T p.M1? | Translation Start Site (SNP) | VAF 6/31 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.345); catalogued as COSV58809828; called by muse, mutect2
- ADRA1A | c.1127G>A p.R376H | Missense Mutation (SNP) | VAF 10/60 reads (17%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.714); catalogued as rs140512348, COSV99372231; called by muse, varscan2
- ADRA2A | c.482C>T p.T161M | Missense Mutation (SNP) | VAF 16/92 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54528340; called by muse, mutect2, varscan2
- ADRB2 | c.376G>A p.V126M | Missense Mutation (SNP) | VAF 61/272 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV60005391; called by muse, mutect2, varscan2
- AEBP1 | c.3026G>A p.R1009H | Missense Mutation (SNP) | VAF 22/104 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); catalogued as COSV56256320; called by muse, mutect2, varscan2
- AF196969.1 | c.424C>T p.R142C | Missense Mutation (SNP) | VAF 35/197 reads (18%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.499); catalogued as rs953562416, COSV52141844; called by muse, mutect2, varscan2
- AFF2 | c.18T>A p.F6L | Missense Mutation (SNP) | VAF 96/536 reads (18%) | SIFT tolerated (0.67); PolyPhen benign (0.014); catalogued as rs782754337; called by muse, mutect2
- AFF2 | c.3701C>T p.T1234I | Missense Mutation (SNP) | VAF 20/109 reads (18%) | SIFT tolerated (0.08); PolyPhen benign (0.052); catalogued as rs1225055723; called by muse, mutect2, varscan2
- AFM | c.929G>A p.R310H | Missense Mutation (SNP) | VAF 10/77 reads (13%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.938); catalogued as rs780697944; called by mutect2, varscan2
- AGAP2 | c.2839G>A p.V947M (on ENST00000547588 / NM_001122772.2; = p.V591M on NM_014770.4) | Missense Mutation (SNP) | VAF 23/136 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as rs1454449161; called by muse, mutect2, varscan2
- AGBL1 | c.2087G>A p.R696H | Missense Mutation (SNP) | VAF 19/76 reads (25%) | SIFT tolerated (0.58); PolyPhen benign (0.031); catalogued as rs376573682; called by muse, mutect2, varscan2
- AGBL5 | c.331C>T p.R111C | Missense Mutation (SNP) | VAF 30/158 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs1437800309, COSV59938107; called by muse, mutect2, varscan2
- AGMO | c.208G>A p.D70N | Missense Mutation (SNP) | VAF 31/92 reads (34%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs903237451; called by muse, mutect2, varscan2
- AHNAK | c.4860G>A p.M1620I | Missense Mutation (SNP) | VAF 40/242 reads (17%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as rs1300502968; called by muse, mutect2, varscan2
- AHNAK2 | c.13939A>G p.M4647V | Missense Mutation (SNP) | VAF 18/79 reads (23%) | SIFT tolerated (0.46); PolyPhen benign (0.005); catalogued as rs1471089005; called by muse, mutect2, varscan2
- AK1 | c.85G>A p.V29M | Missense Mutation (SNP) | VAF 14/65 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.723); catalogued as rs150701679; called by muse, mutect2, varscan2
- AKAP13 | c.2997G>T p.K999N | Missense Mutation (SNP) | VAF 3/17 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.655); catalogued as COSV63448466; called by muse, mutect2
- AKAP13 | c.6609G>T p.E2203D (on ENST00000394518 / NM_007200.5; = p.E2207D on NM_006738.6) | Missense Mutation (SNP) | VAF 43/180 reads (24%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.944); catalogued as COSV63456682; called by muse, mutect2, varscan2
- AKAP17A | c.1588C>T p.R530C | Missense Mutation (SNP) | VAF 12/60 reads (20%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.043); catalogued as rs149990639, COSV100002206; called by muse, mutect2, varscan2
- AKAP6 | c.3208G>T p.D1070Y | Missense Mutation (SNP) | VAF 6/31 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as rs764623922; called by mutect2, varscan2
- AKAP9 | c.11249T>C p.L3750P (on ENST00000359028; = p.L3726P on NM_005751.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 16/91 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs750625057, COSV62360012; called by muse, varscan2
- AKNA | c.3751G>T p.D1251Y | Missense Mutation (SNP) | VAF 52/202 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.804); catalogued as COSV56339879; called by muse, mutect2, varscan2
- AKR7A2 | c.862G>A p.A288T | Missense Mutation (SNP) | VAF 12/80 reads (15%) | SIFT tolerated (0.39); PolyPhen benign (0.003); catalogued as rs775556235, COSV52515538; called by mutect2, varscan2
- AL136295.1 | c.844C>T p.R282C | Missense Mutation (SNP) | VAF 55/212 reads (26%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.876); catalogued as COSV55779302, COSV55781760; called by muse, mutect2, varscan2
- AL592490.1 | c.1435C>T p.P479S | Missense Mutation (SNP) | VAF 60/358 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.335); catalogued as rs921988555; called by muse, varscan2
- AL645922.1 | c.2869G>T p.V957F | Missense Mutation (SNP) | VAF 3/16 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.924); catalogued as CM131616; called by muse, mutect2
- ALAS1 | c.223G>A p.V75I | Missense Mutation (SNP) | VAF 16/76 reads (21%) | SIFT tolerated (0.4); PolyPhen benign (0.042); catalogued as COSV59627849; called by muse, mutect2, varscan2
- ALDH1L1 | c.2701G>A p.E901K | Missense Mutation (SNP) | VAF 15/69 reads (22%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.995); catalogued as rs550440307, COSV56410533, COSV56414628; called by muse, mutect2, varscan2
- ALDOB | c.380-1G>T p.X127_splice | Splice Site (SNP) | VAF 8/55 reads (15%) | catalogued as CS156898, COSV100878845; called by muse, varscan2
- ALDOB | c.272G>C p.G91A | Missense Mutation (SNP) | VAF 12/97 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.732); catalogued as COSV66397400; called by muse, mutect2, varscan2
- ALG1 | c.1213G>T p.E405* | Nonsense Mutation (SNP) | VAF 33/163 reads (20%) | catalogued as COSV99275617; called by muse, mutect2, varscan2
- ALG13 | c.1595C>T p.A532V | Missense Mutation (SNP) | VAF 18/151 reads (12%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.974); catalogued as rs1410359826; called by muse, mutect2, varscan2
- ALG3 | c.953C>T p.S318L | Missense Mutation (SNP) | VAF 55/339 reads (16%) | SIFT tolerated (0.15); PolyPhen benign (0.129); catalogued as rs756802179, COSV56614909; called by muse, mutect2, varscan2
- ALMS1 | c.4250G>A p.R1417Q | Missense Mutation (SNP) | VAF 12/59 reads (20%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs771362238, COSV52506470; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ALPK2 | c.5804G>A p.R1935H | Missense Mutation (SNP) | VAF 8/56 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs753524863, COSV100864513; called by mutect2, varscan2
- ALPK2 | c.4076C>T p.A1359V | Missense Mutation (SNP) | VAF 15/80 reads (19%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as rs372041420; called by muse, varscan2
- ALPK2 | c.3982C>A p.L1328I | Missense Mutation (SNP) | VAF 15/78 reads (19%) | SIFT tolerated (0.17); PolyPhen benign (0.131); catalogued as COSV100864282, COSV64491985; called by muse, varscan2
- ALPK2 | c.809T>G p.I270S | Missense Mutation (SNP) | VAF 15/89 reads (17%) | SIFT deleterious (0.04); PolyPhen benign (0.197); catalogued as COSV100864018; called by muse, mutect2, varscan2
- ALPP | c.706G>T p.D236Y | Missense Mutation (SNP) | VAF 27/183 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101235179; called by muse, mutect2, varscan2
- AMBP | c.359C>T p.S120F | Missense Mutation (SNP) | VAF 52/384 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.637); catalogued as rs753980856, COSV99468921; called by muse, varscan2
- AMDHD2 | c.630G>A p.G210= | Splice Region (SNP) | VAF 9/49 reads (18%) | catalogued as COSV99565738; called by muse, mutect2, varscan2
- AMOTL1 | c.2857G>A p.E953K | Missense Mutation (SNP) | VAF 10/50 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.985); catalogued as rs1444041507; called by muse, mutect2, varscan2
- AMPD1 | c.1852G>A p.A618T | Missense Mutation (SNP) | VAF 34/177 reads (19%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.938); catalogued as rs775529261; called by muse, mutect2, varscan2
- AMZ1 | c.1176G>T p.E392D | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT tolerated (0.15); PolyPhen benign (0.003); catalogued as rs1434652825; called by muse, mutect2, varscan2
- ANAPC2 | c.1741C>T p.R581W | Missense Mutation (SNP) | VAF 11/38 reads (29%) | SIFT tolerated (0.19); PolyPhen benign (0.155); catalogued as COSV60570618; called by muse, mutect2, varscan2
- ANAPC4 | c.1067C>T p.S356L | Missense Mutation (SNP) | VAF 34/209 reads (16%) | SIFT deleterious (0.05); PolyPhen benign (0.37); catalogued as rs370638458; called by muse, varscan2
- ANGPTL2 | c.297G>T p.Q99H | Missense Mutation (SNP) | VAF 12/38 reads (32%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.984); catalogued as rs1267131261; called by muse, mutect2, varscan2
- ANGPTL8 | c.553C>T p.R185* | Nonsense Mutation (SNP) | VAF 12/48 reads (25%) | catalogued as rs774587241; called by muse, varscan2
- ANK1 | c.49C>A p.Q17K | Missense Mutation (SNP) | VAF 46/279 reads (16%) | SIFT tolerated, low confidence (0.19); PolyPhen probably damaging (0.932); catalogued as COSV99701691; called by muse, varscan2
- ANK3 | c.10978C>T p.P3660S | Missense Mutation (SNP) | VAF 19/110 reads (17%) | SIFT tolerated, low confidence (0.34); PolyPhen benign (0.015); catalogued as rs916671598; called by muse, mutect2, varscan2
- ANK3 | c.6715C>T p.R2239C | Missense Mutation (SNP) | VAF 43/218 reads (20%) | SIFT tolerated, low confidence (0.29); PolyPhen probably damaging (0.981); catalogued as rs747533848, COSV55066315; called by muse, mutect2, varscan2
- ANKRD10 | c.1103T>G p.I368S | Missense Mutation (SNP) | VAF 31/152 reads (20%) | SIFT tolerated (0.92); PolyPhen benign (0.006); catalogued as COSV57442783; called by muse, mutect2, varscan2
- ANKRD13C | c.725G>A p.R242Q | Missense Mutation (SNP) | VAF 92/432 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs1406275483, COSV52029334; called by muse, mutect2, varscan2
- ANKRD20A1 | c.1943C>A p.S648Y | Missense Mutation (SNP) | VAF 39/405 reads (10%) | SIFT tolerated (0.63); PolyPhen benign (0.001); catalogued as rs1391089833; called by muse, mutect2, varscan2
- ANKRD29 | c.343G>A p.A115T | Missense Mutation (SNP) | VAF 5/44 reads (11%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.997); catalogued as rs1468810824; called by muse, mutect2, varscan2
- ANKRD30A | c.3356C>T p.A1119V (on ENST00000611781; = p.A1063V on NM_052997.2) | Missense Mutation (SNP) | VAF 12/81 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.006); catalogued as rs373946645; called by mutect2, varscan2
- ANKRD33 | c.505C>T p.P169S (on ENST00000340970 / NM_001304459.2; = p.P294S on NM_182608.4) | Missense Mutation (SNP) | VAF 5/21 reads (24%) | SIFT tolerated (0.78); PolyPhen benign (0.001); catalogued as rs879143932, COSV56605410; called by muse, mutect2, varscan2
- ANKRD36B | c.2107C>T p.R703C | Missense Mutation (SNP) | VAF 44/252 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.035); catalogued as rs528773958, COSV99308439; called by muse, mutect2, varscan2
- ANKRD6 | c.926G>A p.S309N | Missense Mutation (SNP) | VAF 18/90 reads (20%) | SIFT tolerated (0.09); PolyPhen benign (0.192); catalogued as COSV60230663; called by muse, varscan2
- ANKS1B | c.2114A>C p.N705T | Missense Mutation (SNP) | VAF 34/178 reads (19%) | SIFT tolerated (0.48); PolyPhen benign (0); catalogued as rs1453011784, COSV61364515; called by muse, mutect2
- ANKS1B | c.1820G>A p.G607D | Missense Mutation (SNP) | VAF 7/45 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.898); catalogued as rs1384260750; called by muse, mutect2, varscan2
- ANKS1B | c.514G>A p.G172R | Missense Mutation (SNP) | VAF 23/130 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61361440, COSV61377004; called by muse, mutect2, varscan2
- ANO2 | c.1129G>T p.G377* (on ENST00000356134 / NM_001278597.3; = p.G381* on NM_001278596.3) | Nonsense Mutation (SNP) | VAF 31/194 reads (16%) | catalogued as COSV59020863, COSV59043946; called by muse, mutect2, varscan2
- ANO2 | c.4C>T p.P2S | Missense Mutation (SNP) | VAF 93/539 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as rs1342077671; called by muse, mutect2, varscan2
- ANO6 | c.279+1G>T p.X93_splice | Splice Site (SNP) | VAF 20/140 reads (14%) | catalogued as rs746802648; called by muse, mutect2, varscan2
- ANO7 | c.774+1G>A p.X258_splice (on ENST00000274979; = p.X204_splice on NM_001370694.2) | Splice Site (SNP) | VAF 17/133 reads (13%) | catalogued as rs747391575; called by muse, varscan2
- ANP32A | c.715C>T p.R239* | Nonsense Mutation (SNP) | VAF 38/199 reads (19%) | catalogued as COSV51189644; called by muse, mutect2, varscan2
- ANXA2 | c.220G>A p.A74T | Missense Mutation (SNP) | VAF 82/358 reads (23%) | SIFT tolerated (0.18); PolyPhen benign (0.113); catalogued as rs774410888, COSV60316814; called by muse, mutect2, varscan2
- AOAH | c.709G>A p.D237N | Missense Mutation (SNP) | VAF 34/204 reads (17%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.996); catalogued as rs766556440; called by muse, mutect2, varscan2
- AOC1 | c.1717C>A p.L573M | Missense Mutation (SNP) | VAF 11/46 reads (24%) | SIFT tolerated (0.25); PolyPhen benign (0.042); catalogued as COSV62868322; called by muse, mutect2
- AP1S2 | c.206C>A p.A69D | Missense Mutation (SNP) | VAF 59/359 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.816); catalogued as COSV61306836; called by muse, mutect2, varscan2
- AP4B1 | c.827G>A p.R276Q | Missense Mutation (SNP) | VAF 32/143 reads (22%) | SIFT tolerated (0.1); PolyPhen benign (0.038); catalogued as rs1301678999, COSV56725059; called by muse, mutect2, varscan2
- APBA2 | c.1106G>T p.G369V | Missense Mutation (SNP) | VAF 18/117 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101258151; called by muse, mutect2, varscan2
- APBA2 | c.1826C>T p.S609L | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.834); catalogued as rs754328467; called by muse, varscan2
- APC | c.6579del p.V2194Ffs*5 | Frame Shift Del (DEL) | VAF 23/154 reads (15%) | catalogued as rs775076289; called by mutect2, pindel, varscan2
- APOBEC3D | c.397G>A p.A133T | Missense Mutation (SNP) | VAF 15/80 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs773235065; called by muse, mutect2, varscan2
- APOBEC3D | c.949G>A p.A317T | Missense Mutation (SNP) | VAF 25/134 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); catalogued as rs1287372773; called by muse, mutect2, varscan2
- APOBEC3F | c.172-1G>T p.X58_splice | Splice Site (SNP) | VAF 37/228 reads (16%) | catalogued as COSV57912230; called by muse, mutect2, varscan2
- APOBR | c.2594C>T p.A865V (on ENST00000431282; = p.A874V on NM_018690.4) | Missense Mutation (SNP) | VAF 14/92 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.062); catalogued as COSV60494974; called by muse, mutect2
- APOF | c.637C>T p.R213* | Nonsense Mutation (SNP) | VAF 24/95 reads (25%) | catalogued as rs1178870851; called by muse, mutect2, varscan2
- APOH | c.415+1G>A p.X139_splice | Splice Site (SNP) | VAF 29/132 reads (22%) | catalogued as rs113148457, COSV52774943; called by muse, mutect2, varscan2
- APOL3 | c.998T>C p.V333A (on ENST00000349314 / NM_145640.2; = p.V262A on NM_014349.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 11/66 reads (17%) | SIFT tolerated (0.05); PolyPhen benign (0.005); catalogued as rs866958976; called by muse, mutect2, varscan2
- APTX | c.8G>A p.R3Q | Missense Mutation (SNP) | VAF 6/51 reads (12%) | SIFT tolerated (0.23); PolyPhen benign (0.006); catalogued as rs746257545, COSV58929793; called by mutect2, varscan2
- AQP6 | c.176C>A p.A59D | Missense Mutation (SNP) | VAF 15/84 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59646290; called by muse, mutect2, varscan2
- AQP7 | c.735G>T p.Q245H | Missense Mutation (SNP) | VAF 9/54 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.489); catalogued as COSV99953455; called by muse, mutect2, varscan2
- AQR | c.1028C>T p.A343V | Missense Mutation (SNP) | VAF 20/144 reads (14%) | SIFT tolerated (0.09); PolyPhen benign (0.006); catalogued as rs745671670; called by muse, mutect2, varscan2
- ARAP2 | c.5033G>T p.R1678M | Missense Mutation (SNP) | VAF 27/120 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.174); catalogued as rs1202584023; called by muse, mutect2, varscan2
- AREL1 | c.1421C>T p.S474L | Missense Mutation (SNP) | VAF 15/77 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.922); catalogued as rs746619206; called by muse, mutect2, varscan2
- ARF5 | c.455C>T p.T152M | Missense Mutation (SNP) | VAF 20/91 reads (22%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.436); catalogued as rs749643254, COSV99133512, COSV99134006; called by muse, mutect2, varscan2
- ARFGAP1 | c.422C>T p.T141M | Missense Mutation (SNP) | VAF 10/58 reads (17%) | SIFT tolerated (0.54); PolyPhen benign (0.003); catalogued as rs377405400; called by mutect2, varscan2
- ARFGAP2 | c.276del p.R93Afs*43 | Frame Shift Del (DEL) | VAF 37/213 reads (17%) | catalogued as rs772728725, COSV54066450; called by mutect2, varscan2
- ARFGEF1 | c.5485C>T p.R1829* | Nonsense Mutation (SNP) | VAF 48/188 reads (26%) | catalogued as COSV51592868; called by muse, mutect2, varscan2
- ARG2 | c.989G>A p.G330E | Missense Mutation (SNP) | VAF 16/87 reads (18%) | SIFT tolerated (0.23); PolyPhen benign (0.045); catalogued as rs1243522412; called by muse, mutect2, varscan2
- ARGLU1 | c.730C>T p.R244* | Nonsense Mutation (SNP) | VAF 132/727 reads (18%) | catalogued as COSV65608745; called by muse, mutect2, varscan2
- ARHGAP11A | c.1954G>T p.V652L | Missense Mutation (SNP) | VAF 8/60 reads (13%) | SIFT tolerated (0.75); PolyPhen benign (0); catalogued as COSV100276629; called by muse, mutect2
- ARHGAP17 | c.2384C>T p.P795L (on ENST00000289968 / NM_001006634.3; = p.P717L on NM_018054.6) | Missense Mutation (SNP) | VAF 32/173 reads (18%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.007); catalogued as rs370125785, COSV51506112; called by muse, mutect2, varscan2
- ARHGAP18 | c.535A>G p.R179G | Missense Mutation (SNP) | VAF 12/113 reads (11%) | SIFT tolerated (0.34); PolyPhen benign (0); catalogued as COSV63763739; called by muse, mutect2, varscan2
- ARHGAP24 | c.807-1G>A p.X269_splice (on ENST00000395184 / NM_001025616.3; = p.X176_splice on NM_031305.3) | Splice Site (SNP) | VAF 31/125 reads (25%) | catalogued as rs148824321; called by muse, mutect2, varscan2
- ARHGAP28 | c.1900C>T p.R634* (on ENST00000383472 / NM_001366230.1; = p.R475* on NM_001010000.3) | Nonsense Mutation (SNP) | VAF 40/232 reads (17%) | catalogued as rs773098375, COSV51644954; called by muse, mutect2, varscan2
- ARHGAP45 | c.475C>T p.R159C | Missense Mutation (SNP) | VAF 10/62 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.981); catalogued as rs1453243150, COSV57434991; called by muse, mutect2
- ARHGEF17 | c.3986G>A p.R1329H | Missense Mutation (SNP) | VAF 17/110 reads (15%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.992); catalogued as rs368051277; called by muse, mutect2, varscan2
- ARHGEF17 | c.5917G>A p.V1973I | Missense Mutation (SNP) | VAF 15/59 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.923); catalogued as rs775654966, COSV55238634; called by muse, mutect2, varscan2
- ARHGEF19 | c.2250C>T p.D750= | Splice Region (SNP) | VAF 17/105 reads (16%) | catalogued as rs542362149; called by muse, mutect2, varscan2
- ARHGEF6 | c.2086C>A p.L696I | Missense Mutation (SNP) | VAF 47/350 reads (13%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs1283392244, COSV99166633; called by muse, mutect2, varscan2
- ARHGEF6 | c.467C>T p.T156M | Missense Mutation (SNP) | VAF 41/228 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.959); catalogued as rs144171880, COSV51690767; called by muse, mutect2, varscan2
- ARHGEF9 | c.1486G>A p.E496K | Missense Mutation (SNP) | VAF 28/134 reads (21%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.097); catalogued as rs1203752009, COSV53637533; called by mutect2, varscan2
- ARID1B | c.2960C>T p.A987V | Missense Mutation (SNP) | VAF 15/58 reads (26%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.06); catalogued as rs750810656, COSV51652326; called by muse, mutect2, varscan2
- ARID1B | c.6096C>A p.C2032* | Nonsense Mutation (SNP) | VAF 20/93 reads (22%) | catalogued as rs1554237925; called by muse, mutect2, varscan2
- ARID2 | c.5035C>T p.R1679W | Missense Mutation (SNP) | VAF 79/290 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs1201192337; called by muse, mutect2, varscan2
- ARID3A | c.1733C>T p.A578V | Missense Mutation (SNP) | VAF 16/101 reads (16%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.063); catalogued as rs150609955; called by muse, mutect2, varscan2
- ARID3C | c.913G>A p.A305T | Missense Mutation (SNP) | VAF 29/150 reads (19%) | SIFT tolerated (0.15); PolyPhen benign (0.023); catalogued as COSV99426883; called by muse, mutect2, varscan2
- ARID5B | c.1730C>T p.S577F | Missense Mutation (SNP) | VAF 22/84 reads (26%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as COSV54427073; called by muse, varscan2
- ARID5B | c.1806G>T p.Q602H | Missense Mutation (SNP) | VAF 12/58 reads (21%) | SIFT tolerated (0.4); PolyPhen benign (0.001); catalogued as COSV54420356; called by muse, varscan2
- ARID5B | c.2243G>A p.R748Q | Missense Mutation (SNP) | VAF 25/90 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1481593361; called by muse, mutect2, varscan2
- ARID5B | c.2465C>T p.S822F | Missense Mutation (SNP) | VAF 20/85 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.48); catalogued as COSV99689476; called by muse, mutect2, varscan2
- ARMC12 | c.722C>T p.P241L (on ENST00000373866 / NM_001286574.2; = p.P268L on NM_145028.5) | Missense Mutation (SNP) | VAF 14/80 reads (18%) | SIFT tolerated (0.09); PolyPhen benign (0.025); catalogued as rs1453850079; called by muse, varscan2
- ARMC9 | c.580A>G p.K194E | Missense Mutation (SNP) | VAF 49/218 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.462); catalogued as COSV63019549; called by muse, mutect2, varscan2
- ARMCX5 | c.299G>A p.R100H | Missense Mutation (SNP) | VAF 13/81 reads (16%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as rs112989637; called by muse, mutect2, varscan2
- ARMH4 | c.1925C>T p.S642L | Missense Mutation (SNP) | VAF 117/617 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.138); catalogued as rs781019905; called by muse, mutect2, varscan2
- ARNT | c.664C>T p.R222C | Missense Mutation (SNP) | VAF 22/114 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1293180795, COSV100591098, COSV100591400; called by muse, mutect2, varscan2
- ARSD | c.1235C>T p.T412M | Missense Mutation (SNP) | VAF 9/48 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs750371469, COSV99472117; called by muse, mutect2, varscan2
- ARSJ | c.847C>T p.R283* | Nonsense Mutation (SNP) | VAF 27/152 reads (18%) | catalogued as rs768960135, COSV59538126, COSV59538717, COSV59540375; called by muse, mutect2, varscan2
- ARSL | c.839C>T p.A280V | Missense Mutation (SNP) | VAF 13/56 reads (23%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs745362620, COSV101140655, COSV66965140; called by muse, mutect2, varscan2
- ARVCF | c.2695+1G>T p.X899_splice | Splice Site (SNP) | VAF 18/87 reads (21%) | catalogued as rs200210011; called by muse, mutect2, varscan2
- ASAH1 | c.182G>A p.G61D | Missense Mutation (SNP) | VAF 49/262 reads (19%) | SIFT tolerated (0.34); PolyPhen benign (0.091); catalogued as rs551102859; called by muse, mutect2, varscan2
- ASAP1 | c.922C>T p.R308W | Missense Mutation (SNP) | VAF 31/192 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.425); catalogued as rs1405718044; called by muse, mutect2, varscan2
- ASAP3 | c.2326C>T p.R776C | Missense Mutation (SNP) | VAF 20/108 reads (19%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as rs768226542, COSV60874029; called by muse, mutect2, varscan2
- ASB2 | c.235G>C p.E79Q | Missense Mutation (SNP) | VAF 9/86 reads (10%) | SIFT tolerated (0.18); PolyPhen benign (0.143); catalogued as rs758225700; called by muse, mutect2, varscan2
- ASF1B | c.111C>T p.D37= | Splice Region (SNP) | VAF 64/343 reads (19%) | catalogued as rs746430062; called by muse, mutect2, varscan2
- ASH1L | c.8866C>T p.R2956* (on ENST00000368346 / NM_001366177.2; = p.R2951* on NM_018489.3) | Nonsense Mutation (SNP) | VAF 26/136 reads (19%) | catalogued as rs776253661, COSV64208132; called by muse, mutect2, varscan2
- ASL | c.1165G>A p.E389K | Missense Mutation (SNP) | VAF 5/27 reads (19%) | SIFT deleterious (0.04); PolyPhen benign (0.044); catalogued as rs1465800300; called by muse, mutect2, varscan2
- ASPH | c.1685G>A p.R562H | Missense Mutation (SNP) | VAF 15/88 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs771474720, COSV65244220; called by muse, mutect2, varscan2
- ASPM | c.8558G>A p.R2853Q | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.97); catalogued as rs148245202; ClinVar: likely benign; called by muse, mutect2, varscan2
- ASPM | c.2561G>A p.R854H | Missense Mutation (SNP) | VAF 37/209 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99660716; called by muse, mutect2, varscan2
- ASPM | c.1896G>T p.E632D | Missense Mutation (SNP) | VAF 168/932 reads (18%) | SIFT tolerated (0.07); PolyPhen benign (0.045); catalogued as COSV54128518; called by muse, mutect2, varscan2
- ASXL3 | c.2840A>T p.K947M | Missense Mutation (SNP) | VAF 41/239 reads (17%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.03); catalogued as COSV52459267; called by muse, mutect2, varscan2
- ATAT1 | c.859C>T p.P287S | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT tolerated (0.31); PolyPhen benign (0.021); catalogued as rs1422373200; called by mutect2, varscan2
- ATF1 | c.425C>A p.T142N | Missense Mutation (SNP) | VAF 21/122 reads (17%) | SIFT tolerated (0.31); PolyPhen benign (0.031); catalogued as COSV100016316, COSV50394591; called by muse, mutect2, varscan2
- ATF2 | c.1082G>A p.R361Q | Missense Mutation (SNP) | VAF 63/270 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51368882; called by muse, mutect2, varscan2
- ATG10 | c.41G>A p.R14H | Missense Mutation (SNP) | VAF 54/344 reads (16%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs768215835; called by muse, varscan2
- ATG4A | c.154C>T p.R52C | Missense Mutation (SNP) | VAF 49/331 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs756276852, COSV58966491; called by muse, mutect2, varscan2
- ATN1 | c.1414G>A p.A472T | Missense Mutation (SNP) | VAF 22/160 reads (14%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.003); catalogued as rs782802249; called by muse, mutect2, varscan2
- ATN1 | c.2677C>T p.H893Y | Missense Mutation (SNP) | VAF 21/84 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as COSV100755650; called by muse, mutect2, varscan2
- ATP10A | c.2912G>T p.S971I | Missense Mutation (SNP) | VAF 23/96 reads (24%) | SIFT tolerated (0.08); PolyPhen benign (0.099); catalogued as COSV63517348; called by muse, mutect2, varscan2
- ATP10A | c.640G>A p.G214S | Missense Mutation (SNP) | VAF 20/96 reads (21%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.473); catalogued as rs747742914, COSV63513196, COSV63517069; called by muse, mutect2
- ATP2A3 | c.1859G>A p.R620H | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs767243587, COSV59229729; called by muse, mutect2, varscan2
- ATP2B2 | c.3361C>T p.R1121* (on ENST00000352432; = p.R1087* on NM_001683.5) | Nonsense Mutation (SNP) | VAF 9/43 reads (21%) | catalogued as COSV100659755, COSV100660044; called by muse, mutect2, varscan2
- ATP2B2 | c.2572C>T p.R858C (on ENST00000352432; = p.R824C on NM_001683.5) | Missense Mutation (SNP) | VAF 33/172 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1559538483; called by muse, mutect2, varscan2
- ATP2B4 | c.2002G>A p.V668M | Missense Mutation (SNP) | VAF 10/40 reads (25%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.92); catalogued as rs1364785541; called by muse, varscan2
- ATP4A | c.2987G>A p.R996Q | Missense Mutation (SNP) | VAF 20/102 reads (20%) | SIFT tolerated (0.1); PolyPhen benign (0.421); catalogued as rs200601286; called by muse, mutect2, varscan2
- ATP4A | c.1121C>T p.A374V | Missense Mutation (SNP) | VAF 29/156 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52872456; called by muse, mutect2, varscan2
- ATP6V0A2 | c.1177G>T p.E393* | Nonsense Mutation (SNP) | VAF 36/175 reads (21%) | catalogued as COSV100376747; called by muse, mutect2, varscan2
- ATP6V1A | c.693G>T p.Q231H | Missense Mutation (SNP) | VAF 46/239 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1419073540; called by muse, mutect2, varscan2
- ATP7B | c.1073G>A p.C358Y | Missense Mutation (SNP) | VAF 10/55 reads (18%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as CD082052; called by muse, mutect2, varscan2
- ATP8A2 | c.461C>A p.T154K | Missense Mutation (SNP) | VAF 26/170 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.24); catalogued as COSV54981182; called by muse, varscan2
- ATP8B1 | c.3431A>G p.Y1144C | Missense Mutation (SNP) | VAF 66/346 reads (19%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.998); catalogued as rs750281258, COSV52174356; called by muse, mutect2, varscan2
- ATP8B1 | c.392A>G p.Q131R | Missense Mutation (SNP) | VAF 56/264 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV52180208; called by muse, mutect2, varscan2
- ATP8B2 | c.1148G>A p.R383H (on ENST00000672630; = p.R350H on NM_001367934.1 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 12/44 reads (27%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); catalogued as COSV59244890, COSV59249005; called by muse, mutect2
- ATP9B | c.556C>A p.L186M | Missense Mutation (SNP) | VAF 25/145 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56960220; called by muse, varscan2
- ATR | c.3074G>A p.R1025H | Missense Mutation (SNP) | VAF 14/74 reads (19%) | SIFT tolerated (0.08); PolyPhen benign (0.074); catalogued as rs771309709; called by muse, mutect2, varscan2
- ATRIP | c.1724C>A p.T575N | Missense Mutation (SNP) | VAF 11/73 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.051); catalogued as rs765469662; called by muse, mutect2, varscan2
- ATRN | c.517C>T p.R173C | Missense Mutation (SNP) | VAF 54/326 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs758948800, COSV53527986; called by muse, mutect2, varscan2
- AVL9 | c.500C>A p.A167D | Missense Mutation (SNP) | VAF 18/124 reads (15%) | SIFT tolerated (0.5); PolyPhen benign (0.005); catalogued as COSV59463824; called by muse, mutect2, varscan2
- AVP | c.95C>T p.A32V | Missense Mutation (SNP) | VAF 11/57 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.703); catalogued as rs1384371077, COSV66671700; called by muse, mutect2, varscan2
- AWAT2 | c.628C>T p.R210C | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as rs762323805, COSV52142983, COSV52144009; called by muse, mutect2
- AZGP1 | c.779G>A p.G260D | Missense Mutation (SNP) | VAF 13/59 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.949); catalogued as COSV52797592; called by muse, mutect2, varscan2
- B3GALT1 | c.185C>T p.S62F | Missense Mutation (SNP) | VAF 21/168 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.11); catalogued as COSV104400142; called by muse, mutect2, varscan2
- B3GAT1 | c.101C>T p.A34V | Missense Mutation (SNP) | VAF 18/83 reads (22%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.017); catalogued as rs200111033, COSV56995067, COSV99074089; called by muse, mutect2, varscan2
- B3GNT4 | c.658G>A p.D220N | Missense Mutation (SNP) | VAF 17/89 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as rs778104699, COSV57336304; called by muse, mutect2, varscan2
- B3GNT4 | c.865C>T p.R289W | Missense Mutation (SNP) | VAF 46/208 reads (22%) | SIFT deleterious (0.03); PolyPhen benign (0.003); catalogued as COSV57336878; called by muse, varscan2
- B4GALNT2 | c.908G>A p.R303H | Missense Mutation (SNP) | VAF 21/135 reads (16%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.719); catalogued as rs752552356, COSV55928493; called by muse, mutect2, varscan2
- BABAM1 | c.77G>A p.R26H | Missense Mutation (SNP) | VAF 8/29 reads (28%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.001); catalogued as rs758526214; called by mutect2, varscan2
- BACH2 | c.1846C>T p.P616S | Missense Mutation (SNP) | VAF 31/182 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.023); catalogued as COSV57585898; called by muse, mutect2, varscan2
- BAG3 | c.1258C>A p.P420T | Missense Mutation (SNP) | VAF 8/52 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as COSV64842134; called by muse, mutect2, varscan2
- BANK1 | c.309G>T p.K103N | Missense Mutation (SNP) | VAF 31/159 reads (19%) | SIFT tolerated (0.17); PolyPhen benign (0.01); catalogued as COSV100536770; called by muse, mutect2, varscan2
- BAZ2A | c.4796G>A p.R1599Q | Missense Mutation (SNP) | VAF 5/40 reads (13%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.974); catalogued as rs1460532285, COSV99058578; called by muse, mutect2, varscan2
- BAZ2A | c.3202C>T p.R1068C | Missense Mutation (SNP) | VAF 16/94 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.099); catalogued as rs374665531; called by muse, mutect2, varscan2
- BBOX1 | c.1045C>T p.R349* | Nonsense Mutation (SNP) | VAF 40/194 reads (21%) | catalogued as rs200897398, COSV54194993; called by muse, mutect2, varscan2
- BCAR1 | c.274C>A p.P92T | Missense Mutation (SNP) | VAF 28/160 reads (18%) | SIFT tolerated (0.26); PolyPhen benign (0); catalogued as COSV50784168; called by muse, varscan2
- BCAR1 | c.214G>A p.A72T | Missense Mutation (SNP) | VAF 22/106 reads (21%) | SIFT tolerated (0.15); PolyPhen benign (0.006); catalogued as rs1193484213, COSV99366276; called by muse, varscan2
- BCAR3 | c.113G>A p.R38H | Missense Mutation (SNP) | VAF 27/90 reads (30%) | SIFT tolerated, low confidence (0.39); PolyPhen benign (0.001); catalogued as rs202034375; called by muse, mutect2, varscan2
- BCL2L14 | c.218C>A p.P73H | Missense Mutation (SNP) | VAF 12/106 reads (11%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.939); catalogued as COSV53789129; called by muse, mutect2, varscan2
- BCLAF1 | c.2318G>A p.R773K | Missense Mutation (SNP) | VAF 29/186 reads (16%) | SIFT tolerated (0.43); PolyPhen benign (0.173); catalogued as COSV50357417, COSV50359749; called by muse, mutect2, varscan2
- BDH1 | c.344G>A p.C115Y | Missense Mutation (SNP) | VAF 15/97 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.903); catalogued as rs1351372024; called by muse, mutect2, varscan2
- BDKRB1 | c.463C>T p.R155W | Missense Mutation (SNP) | VAF 10/42 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.766); catalogued as rs200573342; called by muse, mutect2, varscan2
- BDP1 | c.2531C>T p.A844V | Missense Mutation (SNP) | VAF 22/146 reads (15%) | SIFT tolerated (0.25); PolyPhen benign (0.015); catalogued as rs777743338; called by muse, varscan2
- BDP1 | c.2844G>T p.K948N | Missense Mutation (SNP) | VAF 24/165 reads (15%) | SIFT tolerated (0.48); PolyPhen benign (0.006); catalogued as rs752797411; called by muse, mutect2, varscan2
- BEND6 | c.668C>A p.A223D | Missense Mutation (SNP) | VAF 35/133 reads (26%) | SIFT tolerated (0.36); PolyPhen possibly damaging (0.9); catalogued as rs1255812154; called by muse, mutect2, varscan2
- BEST2 | c.934G>A p.D312N | Missense Mutation (SNP) | VAF 68/321 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV99076276; called by muse, mutect2, varscan2
- BEST4 | c.449G>A p.R150H | Missense Mutation (SNP) | VAF 5/19 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1438469123; called by muse, mutect2, varscan2
- BICD2 | c.1127C>T p.T376M | Missense Mutation (SNP) | VAF 16/72 reads (22%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.596); catalogued as rs200325192; ClinVar: likely benign; called by muse, mutect2, varscan2
- BICD2 | c.368C>T p.T123M | Missense Mutation (SNP) | VAF 26/130 reads (20%) | SIFT deleterious (0.03); PolyPhen benign (0.039); catalogued as rs372717499; ClinVar: uncertain significance; called by muse, varscan2
- BICDL1 | c.704G>A p.R235Q | Missense Mutation (SNP) | VAF 8/71 reads (11%) | SIFT tolerated (0.07); PolyPhen benign (0.184); catalogued as rs746531972; called by mutect2, varscan2
- BICDL2 | c.1039C>T p.R347* | Nonsense Mutation (SNP) | VAF 37/186 reads (20%) | catalogued as rs1452203269; called by muse, mutect2, varscan2
- BICDL2 | c.220C>T p.R74* | Nonsense Mutation (SNP) | VAF 3/15 reads (20%) | catalogued as rs1375074228; called by muse, mutect2
- BIRC6 | c.754G>A p.A252T | Missense Mutation (SNP) | VAF 37/190 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.724); catalogued as COSV101428498; called by muse, mutect2, varscan2
- BIRC6 | c.11828T>C p.I3943T | Missense Mutation (SNP) | VAF 23/119 reads (19%) | SIFT tolerated (0.23); PolyPhen benign (0.003); catalogued as rs1387987027; called by muse, mutect2, varscan2
- BIVM-ERCC5 | c.691G>A p.G231R | Missense Mutation (SNP) | VAF 50/294 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV57282077; called by muse, mutect2, varscan2
- BLZF1 | c.475C>T p.R159C | Missense Mutation (SNP) | VAF 29/172 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.708); catalogued as rs1252405250, COSV61392922; called by muse, mutect2, varscan2
- BMP1 | c.1542G>T p.K514N | Missense Mutation (SNP) | VAF 12/64 reads (19%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.479); catalogued as COSV60483343; called by muse, mutect2, varscan2
- BMP5 | c.422C>A p.P141H | Missense Mutation (SNP) | VAF 12/53 reads (23%) | SIFT deleterious (0.03); PolyPhen benign (0.208); catalogued as COSV63703507; called by muse, mutect2, varscan2
- BNC1 | c.1465C>T p.L489F | Missense Mutation (SNP) | VAF 20/94 reads (21%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.973); catalogued as COSV61759143; called by muse, mutect2, varscan2
- BOLA1 | c.181C>T p.P61S | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.968); catalogued as COSV64966840; called by muse, mutect2, varscan2
- BPGM | c.62G>A p.R21H | Missense Mutation (SNP) | VAF 15/116 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as rs757985056; called by muse, mutect2, varscan2
- BPIFB3 | c.232G>T p.G78C | Missense Mutation (SNP) | VAF 37/270 reads (14%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (1); catalogued as COSV64957094; called by muse, mutect2, varscan2
- BPIFC | c.929C>T p.S310F | Missense Mutation (SNP) | VAF 24/172 reads (14%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.924); catalogued as COSV55916631; called by muse, mutect2, varscan2
- BRCA2 | c.8918G>A p.R2973H | Missense Mutation (SNP) | VAF 32/175 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs80359143, COSV66461060; ClinVar: conflicting interpretations of pathogenicity / likely benign / uncertain significance; called by muse, mutect2, varscan2
- BRCC3 | c.178C>T p.R60C | Missense Mutation (SNP) | VAF 134/668 reads (20%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0.005); catalogued as rs782698211, COSV57462065; called by muse, varscan2
- BRD1 | c.538G>A p.A180T | Missense Mutation (SNP) | VAF 12/84 reads (14%) | SIFT tolerated (0.53); PolyPhen benign (0.118); catalogued as rs111730431; called by mutect2, varscan2
- BRD4 | c.3139C>T p.R1047W | Missense Mutation (SNP) | VAF 23/114 reads (20%) | SIFT tolerated, low confidence (0.09); PolyPhen possibly damaging (0.853); catalogued as rs1373343624, COSV54585291; called by muse, mutect2, varscan2
- BRDT | c.580G>T p.G194* | Nonsense Mutation (SNP) | VAF 38/181 reads (21%) | catalogued as COSV100746604; called by muse, mutect2, varscan2
- BRI3 | c.343C>T p.R115* | Nonsense Mutation (SNP) | VAF 54/272 reads (20%) | catalogued as rs748283835; called by muse, mutect2, varscan2
- BRINP1 | c.65C>A p.P22H | Missense Mutation (SNP) | VAF 13/77 reads (17%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.346); catalogued as COSV56301159; called by muse, varscan2
- BRMS1 | c.710C>A p.S237Y | Missense Mutation (SNP) | VAF 46/202 reads (23%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.854); catalogued as COSV60928478; called by muse, mutect2, varscan2
- BRMS1 | c.640G>A p.V214M | Missense Mutation (SNP) | VAF 26/161 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as rs199579517; called by muse, mutect2, varscan2
- BRPF3 | c.734G>A p.G245D | Missense Mutation (SNP) | VAF 24/157 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99045651; called by muse, mutect2, varscan2
- BRSK2 | c.488C>T p.A163V | Missense Mutation (SNP) | VAF 41/217 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.869); catalogued as rs1035544645; called by muse, varscan2
- BRSK2 | c.1787C>T p.T596M | Missense Mutation (SNP) | VAF 18/90 reads (20%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.535); catalogued as rs1416784207, COSV57542658; called by muse, mutect2, varscan2
- BRWD1 | c.3671C>T p.A1224V | Missense Mutation (SNP) | VAF 56/268 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs1408247256, COSV60898570; called by muse, mutect2, varscan2
- BRWD1 | c.2087G>A p.S696N | Missense Mutation (SNP) | VAF 21/103 reads (20%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.796); catalogued as COSV60893296; called by muse, mutect2, varscan2
- BRWD1 | c.1603G>T p.D535Y | Missense Mutation (SNP) | VAF 39/203 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV60899219; called by muse, mutect2, varscan2
- BRWD3 | c.2800C>T p.R934* | Nonsense Mutation (SNP) | VAF 48/238 reads (20%) | catalogued as COSV100956501; called by muse, mutect2, varscan2
- BSN | c.1691C>A p.P564H | Missense Mutation (SNP) | VAF 8/48 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.205); catalogued as COSV56516629; called by muse, mutect2, varscan2
- BTBD7 | c.3313A>G p.T1105A | Missense Mutation (SNP) | VAF 45/196 reads (23%) | SIFT tolerated, low confidence (0.99); PolyPhen benign (0); catalogued as rs1440567327; called by muse, mutect2, varscan2
- BUB1B | c.2309G>A p.R770Q | Missense Mutation (SNP) | VAF 59/326 reads (18%) | SIFT tolerated (0.71); PolyPhen benign (0); catalogued as rs1422532977; called by muse, mutect2, varscan2
- BVES | c.351+1G>A p.X117_splice | Splice Site (SNP) | VAF 14/157 reads (9%) | catalogued as rs1226101517; called by muse, mutect2
- C11orf45 | c.35G>T p.S12I | Missense Mutation (SNP) | VAF 12/64 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.354); catalogued as COSV100171551; called by muse, mutect2, varscan2
- C12orf42 | c.987G>T p.K329N | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT deleterious (0.04); PolyPhen benign (0.283); catalogued as rs780263324, COSV100172552; called by mutect2, varscan2
- C14orf93 | c.1412G>A p.R471H | Missense Mutation (SNP) | VAF 51/250 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as rs759834095; called by muse, mutect2, varscan2
- C16orf46 | c.184A>G p.I62V | Missense Mutation (SNP) | VAF 47/266 reads (18%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs35142000; called by muse, varscan2
- C16orf89 | c.808C>T p.R270W | Missense Mutation (SNP) | VAF 8/33 reads (24%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.791); catalogued as rs537472512, COSV60125445; called by muse, mutect2, varscan2
- C17orf97 | c.536C>T p.P179L | Missense Mutation (SNP) | VAF 42/205 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.786); catalogued as rs782637295; called by muse, mutect2, varscan2
- C1GALT1C1L | c.598G>A p.D200N | Missense Mutation (SNP) | VAF 44/205 reads (21%) | SIFT tolerated (0.74); PolyPhen benign (0); catalogued as rs374217822; called by muse, mutect2, varscan2
- C1QTNF9B | c.103G>A p.G35S | Missense Mutation (SNP) | VAF 65/379 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs143076333; called by muse, mutect2, varscan2
- C1orf109 | c.455C>T p.S152L | Missense Mutation (SNP) | VAF 27/123 reads (22%) | SIFT tolerated (0.23); PolyPhen benign (0.001); catalogued as rs769460024, COSV63657147; called by muse, mutect2, varscan2
- C1orf127 | c.1012G>T p.A338S | Missense Mutation (SNP) | VAF 40/206 reads (19%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.987); catalogued as COSV65436908; called by muse, mutect2, varscan2
- C1orf87 | c.818C>A p.A273D | Missense Mutation (SNP) | VAF 36/215 reads (17%) | SIFT tolerated (0.31); PolyPhen benign (0.003); catalogued as rs1341810949; called by muse, mutect2, varscan2
- C20orf194 | c.3327+1G>A p.X1109_splice | Splice Site (SNP) | VAF 23/87 reads (26%) | catalogued as rs1450341307, COSV52694658, COSV52698188; called by muse, mutect2, varscan2
- C20orf96 | c.541G>T p.E181* (on ENST00000360321 / NM_153269.3; = p.E180* on NM_080571.1) | Nonsense Mutation (SNP) | VAF 131/715 reads (18%) | catalogued as COSV100826687, COSV64403818; called by muse, mutect2, varscan2
- C22orf39 | c.260C>T p.P87L | Missense Mutation (SNP) | VAF 5/32 reads (16%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1302087910, COSV100287038; called by muse, mutect2, varscan2
- C3orf84 | c.181C>T p.R61C | Missense Mutation (SNP) | VAF 45/203 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs371051845, COSV100234052; called by muse, mutect2, varscan2
- C4B | c.3667G>T p.E1223* | Nonsense Mutation (SNP) | VAF 14/121 reads (12%) | catalogued as COSV70313304; called by muse, mutect2, varscan2
- C6orf118 | c.620C>T p.A207V | Missense Mutation (SNP) | VAF 9/58 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV57818306; called by muse, mutect2, varscan2
- C6orf15 | c.55C>A p.L19I | Missense Mutation (SNP) | VAF 7/44 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV52537188; called by muse, mutect2, varscan2
- C6orf58 | c.1A>G p.M1? | Translation Start Site (SNP) | VAF 10/69 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.622); catalogued as rs1451475456; called by muse, mutect2
- C7orf57 | c.193G>T p.E65* | Nonsense Mutation (SNP) | VAF 12/100 reads (12%) | catalogued as COSV62364139; called by muse, mutect2, varscan2
- C8orf74 | c.715C>T p.R239C | Missense Mutation (SNP) | VAF 22/105 reads (21%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as rs765461161, COSV100261971; called by muse, varscan2
- C8orf76 | c.297G>T p.Q99H | Missense Mutation (SNP) | VAF 57/315 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.919); catalogued as COSV99415037; called by muse, mutect2, varscan2
- C9 | c.550G>A p.D184N | Missense Mutation (SNP) | VAF 78/434 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.129); catalogued as COSV54682641; called by muse, mutect2, varscan2
- C9orf131 | c.1352C>T p.T451I | Missense Mutation (SNP) | VAF 14/77 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.037); catalogued as rs371149221; called by muse, varscan2
- CA14 | c.920C>A p.A307D | Missense Mutation (SNP) | VAF 71/374 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.216); catalogued as COSV52529079; called by muse, mutect2, varscan2
- CA3 | c.347C>T p.A116V | Missense Mutation (SNP) | VAF 21/126 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.869); catalogued as rs770535043, COSV53409913; called by muse, mutect2, varscan2
- CAAP1 | c.531dup p.L178Tfs*11 | Frame Shift Ins (INS) | VAF 46/321 reads (14%) | catalogued as rs1312369665; called by mutect2, pindel, varscan2
- CABIN1 | c.4066G>A p.D1356N | Missense Mutation (SNP) | VAF 11/53 reads (21%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.996); catalogued as COSV99573903; called by muse, mutect2, varscan2
- CABLES1 | c.980A>G p.N327S (on ENST00000256925 / NM_001100619.2; = p.N62S on NM_138375.2) | Missense Mutation (SNP) | VAF 27/142 reads (19%) | SIFT tolerated (0.18); PolyPhen benign (0.158); catalogued as rs1414199852; called by muse, mutect2, varscan2
- CABP5 | c.312G>A p.M104I | Missense Mutation (SNP) | VAF 33/159 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV53152742; called by muse, mutect2, varscan2
- CACFD1 | c.382G>A p.A128T | Missense Mutation (SNP) | VAF 13/73 reads (18%) | SIFT tolerated (0.14); PolyPhen benign (0.34); catalogued as rs782205792, COSV52468775; called by muse, mutect2, varscan2
- CACNA1C | c.6571C>T p.R2191W (on ENST00000399634 / NM_001167625.1; = p.R2120W on NM_000719.7) | Missense Mutation (SNP) | VAF 21/74 reads (28%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.109); catalogued as COSV59708706; called by muse, varscan2
- CACNA1D | c.3259G>A p.V1087I (on ENST00000350061 / NM_001128840.3; = p.V1107I on NM_000720.4) | Missense Mutation (SNP) | VAF 20/126 reads (16%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.968); catalogued as rs768995869, COSV55445410; called by muse, mutect2, varscan2
- CACNA1E | c.5881C>T p.Q1961* | Nonsense Mutation (SNP) | VAF 23/129 reads (18%) | catalogued as COSV62381081; called by muse, mutect2, varscan2
- CACNA1I | c.2161G>A p.G721R | Missense Mutation (SNP) | VAF 10/70 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1322280833; called by muse, mutect2
- CADPS | c.3217G>A p.A1073T | Missense Mutation (SNP) | VAF 21/110 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as rs147087123; called by muse, varscan2
- CADPS2 | c.2809C>T p.R937C | Missense Mutation (SNP) | VAF 22/108 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs200436780; called by muse, varscan2
- CALD1 | c.307C>T p.R103C | Missense Mutation (SNP) | VAF 13/74 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs369898278; called by muse, mutect2, varscan2
- CALD1 | c.1204A>G p.T402A | Missense Mutation (SNP) | VAF 105/526 reads (20%) | SIFT tolerated, low confidence (0.49); PolyPhen benign (0); catalogued as rs201623086; called by muse, mutect2, varscan2
- CALR | c.631C>T p.P211S | Missense Mutation (SNP) | VAF 27/152 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.643); catalogued as rs1285301824; called by muse, mutect2, varscan2
- CAMTA1 | c.2896G>T p.D966Y | Missense Mutation (SNP) | VAF 34/220 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100347980; called by muse, mutect2, varscan2
- CAND2 | c.1435G>T p.V479L (on ENST00000456430 / NM_001162499.2; = p.V386L on NM_012298.3) | Missense Mutation (SNP) | VAF 10/46 reads (22%) | SIFT tolerated (0.14); PolyPhen benign (0.007); catalogued as rs1451986113; called by muse, varscan2
- CAND2 | c.1591G>A p.A531T (on ENST00000456430 / NM_001162499.2; = p.A438T on NM_012298.3) | Missense Mutation (SNP) | VAF 9/42 reads (21%) | SIFT tolerated (0.15); PolyPhen benign (0.007); catalogued as COSV55987733; called by muse, varscan2
- CAND2 | c.1865G>A p.R622Q (on ENST00000456430 / NM_001162499.2; = p.R529Q on NM_012298.3) | Missense Mutation (SNP) | VAF 7/24 reads (29%) | SIFT tolerated (0.11); PolyPhen benign (0.154); catalogued as rs780125791; called by mutect2, varscan2
- CANT1 | c.316C>T p.R106* | Nonsense Mutation (SNP) | VAF 19/85 reads (22%) | catalogued as rs372332465; called by muse, mutect2, varscan2
- CAPN12 | c.830G>A p.R277Q | Missense Mutation (SNP) | VAF 11/59 reads (19%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.942); catalogued as rs754654701, COSV61016683; called by muse, mutect2, varscan2
- CAPN12 | c.686G>A p.R229H | Missense Mutation (SNP) | VAF 13/62 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.963); catalogued as rs368380755; called by muse, mutect2, varscan2
- CAPN13 | c.785G>A p.R262Q | Missense Mutation (SNP) | VAF 16/83 reads (19%) | SIFT tolerated (0.17); PolyPhen benign (0.185); catalogued as rs771573266, COSV54432647; called by muse, mutect2, varscan2
- CAPNS2 | c.37C>T p.R13* | Nonsense Mutation (SNP) | VAF 23/120 reads (19%) | catalogued as COSV100044897, COSV50894557; called by muse, mutect2, varscan2
- CARD16 | c.529T>C p.S177P | Missense Mutation (SNP) | VAF 22/109 reads (20%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.02); catalogued as rs1412434781; called by muse, varscan2
- CARD6 | c.2092G>A p.A698T | Missense Mutation (SNP) | VAF 9/34 reads (26%) | SIFT tolerated (0.2); PolyPhen benign (0.005); catalogued as rs187034976; called by muse, mutect2, varscan2
- CARNS1 | c.581C>T p.A194V | Missense Mutation (SNP) | VAF 28/150 reads (19%) | SIFT tolerated (0.17); PolyPhen benign (0.028); catalogued as rs371047026; called by muse, varscan2
- CARNS1 | c.622G>A p.E208K | Missense Mutation (SNP) | VAF 30/174 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV57130664; called by muse, varscan2
- CARNS1 | c.1261C>T p.H421Y | Missense Mutation (SNP) | VAF 34/135 reads (25%) | SIFT tolerated (0.37); PolyPhen benign (0.009); catalogued as rs1441616258; called by muse, varscan2
- CASKIN1 | c.3449G>A p.R1150H | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs1326476766; called by muse, varscan2
- CASP2 | c.335G>T p.G112V | Missense Mutation (SNP) | VAF 74/383 reads (19%) | SIFT tolerated (0.21); PolyPhen benign (0.079); catalogued as COSV60082640; called by muse, mutect2, varscan2
- CASP2 | c.1228G>A p.V410M | Missense Mutation (SNP) | VAF 17/59 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60083283; called by muse, mutect2, varscan2
- CASP4 | c.4G>T p.A2S | Missense Mutation (SNP) | VAF 16/57 reads (28%) | SIFT tolerated (0.08); PolyPhen benign (0.041); catalogued as rs745849708; called by muse, mutect2, varscan2
- CASP5 | c.1014G>T p.Q338H | Missense Mutation (SNP) | VAF 16/67 reads (24%) | SIFT tolerated (0.51); PolyPhen benign (0.012); catalogued as COSV99507642; called by muse, mutect2, varscan2
- CASP8 | c.1183G>A p.D395N (on ENST00000432109 / NM_033355.3; = p.D412N on NM_001228.4) | Missense Mutation (SNP) | VAF 19/79 reads (24%) | SIFT tolerated (0.14); PolyPhen benign (0.006); catalogued as COSV51856439; called by muse, varscan2
- CASP8AP2 | c.3128G>A p.R1043Q | Missense Mutation (SNP) | VAF 30/142 reads (21%) | SIFT tolerated (0.1); PolyPhen benign (0.042); catalogued as rs369132664; called by muse, varscan2
- CASQ2 | c.25G>A p.V9M | Missense Mutation (SNP) | VAF 19/114 reads (17%) | SIFT tolerated (0.09); PolyPhen benign (0.081); catalogued as COSV54773569; called by muse, mutect2, varscan2
- CATSPER2 | c.7G>A p.A3T | Missense Mutation (SNP) | VAF 56/292 reads (19%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs146757686; called by muse, mutect2, varscan2
- CATSPER4 | c.82C>T p.R28C | Missense Mutation (SNP) | VAF 22/97 reads (23%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0); catalogued as rs200933844; called by muse, mutect2, varscan2
- CATSPER4 | c.385G>T p.D129Y | Missense Mutation (SNP) | VAF 60/512 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100128268; called by muse, varscan2
- CATSPERB | c.2009G>A p.S670N | Missense Mutation (SNP) | VAF 20/108 reads (19%) | SIFT tolerated (0.44); PolyPhen benign (0); catalogued as COSV99831539; called by muse, mutect2, varscan2
- CATSPERE | c.267A>C p.E89D | Missense Mutation (SNP) | VAF 65/380 reads (17%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.543); catalogued as rs780035288; called by muse, varscan2
- CATSPERG | c.2487G>T p.K829N | Missense Mutation (SNP) | VAF 80/380 reads (21%) | SIFT tolerated (0.26); PolyPhen benign (0.124); catalogued as COSV53053656; called by muse, mutect2, varscan2
- CBLB | c.2731C>T p.R911C | Missense Mutation (SNP) | VAF 17/122 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.993); catalogued as rs990086709, COSV51428844; called by muse, mutect2, varscan2
- CBLL1 | c.655C>T p.R219C | Missense Mutation (SNP) | VAF 34/167 reads (20%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.872); catalogued as rs1562866023, COSV56028296; called by muse, mutect2, varscan2
- CBY1 | c.274C>T p.R92W | Missense Mutation (SNP) | VAF 27/212 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.855); catalogued as rs758699145; called by muse, varscan2
- CC2D2A | c.307C>T p.R103C | Missense Mutation (SNP) | VAF 52/216 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as rs367699902, COSV67503463; called by muse, mutect2, varscan2
- CCAR1 | c.958C>T p.R320C | Missense Mutation (SNP) | VAF 27/137 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.386); catalogued as rs766304257; called by mutect2, varscan2
- CCAR1 | c.1952G>A p.R651Q | Missense Mutation (SNP) | VAF 33/146 reads (23%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.992); catalogued as rs1221967997, COSV56269025, COSV99770445; called by muse, mutect2, varscan2
- CCAR2 | c.1513dup p.L505Pfs*32 | Frame Shift Ins (INS) | VAF 32/205 reads (16%) | catalogued as rs748274275; called by mutect2, varscan2
- CCBE1 | c.818C>T p.P273L | Missense Mutation (SNP) | VAF 6/44 reads (14%) | SIFT deleterious (0.04); PolyPhen benign (0.444); catalogued as COSV67949473; called by muse, varscan2
- CCDC114 | c.982G>A p.A328T | Missense Mutation (SNP) | VAF 11/49 reads (22%) | SIFT tolerated (0.61); PolyPhen benign (0); catalogued as rs561780439, COSV59557019; called by muse, mutect2, varscan2
- CCDC120 | c.202C>T p.P68S | Missense Mutation (SNP) | VAF 6/35 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1557080147; called by muse, mutect2, varscan2
- CCDC121 | c.557G>A p.R186Q | Missense Mutation (SNP) | VAF 53/237 reads (22%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs374230249; called by muse, mutect2, varscan2
- CCDC146 | c.1219C>T p.R407* | Nonsense Mutation (SNP) | VAF 35/175 reads (20%) | catalogued as rs754079533, COSV53551543; called by muse, mutect2, varscan2
- CCDC157 | c.2101C>T p.P701S | Missense Mutation (SNP) | VAF 14/77 reads (18%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.019); catalogued as rs769745656; called by muse, mutect2, varscan2
- CCDC189 | c.487G>A p.V163M | Missense Mutation (SNP) | VAF 28/145 reads (19%) | SIFT deleterious (0.03); PolyPhen benign (0.236); catalogued as rs753229558; called by muse, mutect2, varscan2
- CCDC22 | c.52G>A p.A18T | Missense Mutation (SNP) | VAF 25/138 reads (18%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.516); catalogued as rs1557112812; called by muse, mutect2, varscan2
- CCDC27 | c.317C>T p.T106M | Missense Mutation (SNP) | VAF 4/27 reads (15%) | SIFT tolerated (0.74); PolyPhen benign (0.003); catalogued as rs185617592, COSV53899594; called by mutect2, varscan2
- CCDC27 | c.1091C>T p.S364F | Missense Mutation (SNP) | VAF 66/264 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.051); catalogued as COSV53902902; called by muse, mutect2, varscan2
- CCDC38 | c.515C>A p.S172Y | Missense Mutation (SNP) | VAF 134/606 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs758778174; called by muse, mutect2, varscan2
- CCDC42 | c.695G>A p.R232H | Missense Mutation (SNP) | VAF 20/101 reads (20%) | SIFT tolerated (0.09); PolyPhen benign (0.007); catalogued as rs571535127, COSV53449391; called by muse, mutect2, varscan2
- CCDC68 | c.324G>T p.E108D | Missense Mutation (SNP) | VAF 66/319 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as rs1414967780; called by muse, mutect2, varscan2
- CCDC74A | c.343G>A p.A115T | Missense Mutation (SNP) | VAF 8/78 reads (10%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs532077892; called by mutect2, varscan2
- CCDC74B | c.343G>A p.A115T | Missense Mutation (SNP) | VAF 10/94 reads (11%) | SIFT tolerated (0.96); PolyPhen benign (0); catalogued as rs376855392; called by mutect2, varscan2
- CCDC83 | c.604-1G>T p.X202_splice | Splice Site (SNP) | VAF 34/198 reads (17%) | catalogued as rs1433297999; called by muse, mutect2, varscan2
- CCDC83 | c.796C>T p.R266* (on ENST00000342404 / NM_001286159.2; = p.R297* on NM_173556.5) | Nonsense Mutation (SNP) | VAF 58/400 reads (15%) | catalogued as rs755531984; called by muse, mutect2, varscan2
- CCDC88C | c.3598C>T p.R1200W | Missense Mutation (SNP) | VAF 34/154 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); catalogued as rs961558409; called by muse, varscan2
- CCDC88C | c.3410C>T p.T1137M | Missense Mutation (SNP) | VAF 22/94 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.459); catalogued as rs1173847504, COSV66233428; called by muse, varscan2
- CCL3L3 | c.97G>A p.A33T | Missense Mutation (SNP) | VAF 41/112 reads (37%) | SIFT tolerated (0.07); PolyPhen benign (0.21); catalogued as rs1340370552; called by muse, mutect2, varscan2
- CCNA2 | c.364C>T p.R122C | Missense Mutation (SNP) | VAF 116/621 reads (19%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as rs750866939, COSV52656321; called by muse, mutect2, varscan2
- CCNB1 | c.694C>T p.R232W | Missense Mutation (SNP) | VAF 38/190 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); catalogued as rs745718666, COSV56510605; called by muse, mutect2, varscan2
- CCND2 | c.421C>A p.L141M | Missense Mutation (SNP) | VAF 50/214 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.912); catalogued as COSV99714151; called by muse, varscan2
- CCNDBP1 | c.622A>T p.T208S | Missense Mutation (SNP) | VAF 21/116 reads (18%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs1387705010; called by muse, mutect2, varscan2
- CCNJL | c.1094G>A p.R365H | Missense Mutation (SNP) | VAF 19/80 reads (24%) | SIFT tolerated (0.26); PolyPhen benign (0.005); catalogued as rs377363287; called by muse, mutect2, varscan2
- CCNJL | c.943A>G p.M315V | Missense Mutation (SNP) | VAF 7/39 reads (18%) | SIFT tolerated (0.42); PolyPhen benign (0.013); catalogued as rs752290089; called by muse, mutect2, varscan2
- CCNL1 | c.1313G>A p.R438Q | Missense Mutation (SNP) | VAF 57/298 reads (19%) | SIFT tolerated (0.25); PolyPhen benign (0.102); catalogued as rs748246366, COSV99904457; called by muse, mutect2, varscan2
- CCNL1 | c.77G>T p.S26I | Missense Mutation (SNP) | VAF 8/35 reads (23%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0.001); catalogued as COSV55817408; called by muse, mutect2, varscan2
- CCNT2 | c.1784C>T p.P595L | Missense Mutation (SNP) | VAF 22/109 reads (20%) | SIFT tolerated (0.18); PolyPhen benign (0.023); catalogued as rs185737486; called by muse, mutect2, varscan2
- CCPG1 | c.104G>A p.S35N | Missense Mutation (SNP) | VAF 47/211 reads (22%) | SIFT tolerated (0.7); PolyPhen benign (0.001); catalogued as rs1165669142; called by muse, mutect2, varscan2
- CCRL2 | c.469G>A p.V157I | Missense Mutation (SNP) | VAF 16/74 reads (22%) | SIFT tolerated (0.83); PolyPhen benign (0.265); catalogued as rs201098821; called by muse, varscan2
- CD1C | c.247G>T p.D83Y | Missense Mutation (SNP) | VAF 17/97 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0.022); catalogued as COSV63805793; called by muse, mutect2, varscan2
- CD1E | c.167C>A p.S56* | Nonsense Mutation (SNP) | VAF 38/188 reads (20%) | catalogued as COSV100937011; called by muse, varscan2
- CD200R1L | c.757C>A p.L253M | Missense Mutation (SNP) | VAF 24/117 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs754743078, COSV68004144, COSV68004901; called by muse, mutect2, varscan2
- CD22 | c.2275G>A p.G759S | Missense Mutation (SNP) | VAF 31/157 reads (20%) | SIFT tolerated (0.99); PolyPhen benign (0.001); catalogued as COSV50049744; called by muse, varscan2
- CD5 | c.1280T>C p.M427T | Missense Mutation (SNP) | VAF 17/108 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.236); catalogued as rs780078452; called by muse, mutect2, varscan2
- CD6 | c.1972G>T p.D658Y | Missense Mutation (SNP) | VAF 10/45 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.009); catalogued as COSV57843547; called by muse, mutect2, varscan2
- CD99 | c.203G>A p.R68Q | Missense Mutation (SNP) | VAF 110/701 reads (16%) | SIFT tolerated (0.55); PolyPhen benign (0); catalogued as rs768811289; called by muse, mutect2, varscan2
- CD99L2 | c.577G>A p.A193T | Missense Mutation (SNP) | VAF 6/45 reads (13%) | SIFT tolerated (0.05); PolyPhen benign (0.406); catalogued as rs139219415, COSV60935878; called by muse, mutect2
- CDAN1 | c.2764C>A p.L922M | Missense Mutation (SNP) | VAF 7/52 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.9); catalogued as rs1189474605; called by muse, mutect2, varscan2
- CDAN1 | c.2338C>T p.P780S | Missense Mutation (SNP) | VAF 12/84 reads (14%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs565510675; called by muse, mutect2, varscan2
- CDC27 | c.1816C>A p.L606I | Missense Mutation (SNP) | VAF 31/112 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); catalogued as COSV99294351; called by muse, mutect2, varscan2
- CDC42BPB | c.848C>T p.A283V | Missense Mutation (SNP) | VAF 31/158 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV63474878; called by muse, mutect2, varscan2
- CDC42BPG | c.4484G>T p.S1495I | Missense Mutation (SNP) | VAF 8/33 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.384); catalogued as rs1449763508, COSV61347766; called by muse, mutect2, varscan2
- CDC42BPG | c.670G>A p.G224S | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs182037673; called by mutect2, varscan2
- CDC42EP3 | c.352C>T p.L118F | Missense Mutation (SNP) | VAF 12/67 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV54874148; called by muse, varscan2
- CDC7 | c.1099C>T p.R367C | Missense Mutation (SNP) | VAF 16/73 reads (22%) | SIFT tolerated (0.14); PolyPhen benign (0.025); catalogued as rs541052393, COSV99319827; called by muse, mutect2, varscan2
- CDCP1 | c.2176C>T p.R726* | Nonsense Mutation (SNP) | VAF 30/150 reads (20%) | catalogued as COSV56103982; called by muse, mutect2, varscan2
- CDCP2 | c.241G>A p.D81N | Missense Mutation (SNP) | VAF 25/122 reads (20%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.939); catalogued as rs781568424; called by muse, mutect2, varscan2
- CDH10 | c.1417G>A p.V473M | Missense Mutation (SNP) | VAF 30/141 reads (21%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.931); catalogued as rs199776417, COSV52570793, COSV52580271; called by muse, mutect2, varscan2
- CDH11 | c.83G>A p.R28Q | Missense Mutation (SNP) | VAF 5/13 reads (38%) | SIFT tolerated (0.65); PolyPhen benign (0.063); catalogued as rs527451513, COSV51769963; called by muse, mutect2
- CDH12 | c.121C>T p.H41Y | Missense Mutation (SNP) | VAF 17/71 reads (24%) | SIFT deleterious (0.04); PolyPhen benign (0.011); catalogued as rs776746467, COSV66410447, COSV66438733; called by muse, mutect2, varscan2
- CDH13 | c.328G>A p.V110M | Missense Mutation (SNP) | VAF 8/51 reads (16%) | SIFT tolerated (0.24); PolyPhen benign (0.003); catalogued as rs375168918; called by mutect2, varscan2
- CDH18 | c.2213A>G p.Y738C | Missense Mutation (SNP) | VAF 44/194 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1303963251; called by muse, varscan2
- CDH19 | c.1018C>T p.H340Y | Missense Mutation (SNP) | VAF 59/362 reads (16%) | SIFT tolerated (0.21); PolyPhen benign (0.012); catalogued as rs774239132; called by muse, mutect2, varscan2
- CDH2 | c.622G>A p.G208S | Missense Mutation (SNP) | VAF 7/46 reads (15%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.771); catalogued as COSV52277320; called by muse, mutect2, varscan2
- CDH7 | c.900G>T p.K300N | Missense Mutation (SNP) | VAF 54/474 reads (11%) | SIFT tolerated (0.25); PolyPhen benign (0.236); catalogued as COSV59889968; called by muse, varscan2
- CDH9 | c.2153G>A p.R718Q | Missense Mutation (SNP) | VAF 28/163 reads (17%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs535692550, COSV50266744; called by muse, varscan2
- CDH9 | c.1139C>A p.P380H | Missense Mutation (SNP) | VAF 21/187 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs1329171440; called by muse, mutect2, varscan2
- CDHR2 | c.2108C>T p.T703M | Missense Mutation (SNP) | VAF 38/198 reads (19%) | SIFT tolerated (0.08); PolyPhen benign (0.051); catalogued as rs758415121; called by muse, mutect2, varscan2
- CDK5R1 | c.691T>C p.Y231H | Missense Mutation (SNP) | VAF 28/139 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs532658080; called by muse, mutect2, varscan2
- CDK5RAP1 | c.679G>A p.V227M | Missense Mutation (SNP) | VAF 15/79 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs781287486; called by muse, mutect2, varscan2
- CDKL2 | c.1021G>T p.D341Y | Missense Mutation (SNP) | VAF 24/156 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.962); catalogued as rs750082504; called by muse, mutect2, varscan2
- CDKL3 | c.387G>T p.E129D | Missense Mutation (SNP) | VAF 33/150 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.895); catalogued as rs772295306, COSV99528129; called by muse, mutect2, varscan2
- CDKL3 | c.256G>A p.V86I | Missense Mutation (SNP) | VAF 84/434 reads (19%) | SIFT tolerated (0.44); PolyPhen benign (0.017); catalogued as rs1309395128; called by muse, mutect2, varscan2
- CDKL5 | c.2408C>T p.T803M | Missense Mutation (SNP) | VAF 24/116 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.642); catalogued as rs1005844306, COSV66110500; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CDR2L | c.602C>T p.A201V | Missense Mutation (SNP) | VAF 9/37 reads (24%) | SIFT tolerated (0.62); PolyPhen benign (0); catalogued as COSV61501692; called by muse, mutect2, varscan2
- CDRT1 | c.1295G>A p.R432Q | Missense Mutation (SNP) | VAF 31/180 reads (17%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.992); catalogued as rs764342527, COSV55410733; called by muse, mutect2, varscan2
- CDSN | c.646C>T p.R216C | Missense Mutation (SNP) | VAF 13/88 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.649); catalogued as COSV52539017; called by muse, mutect2
- CDYL | c.1583C>T p.T528M (on ENST00000328908 / NM_001368125.1; = p.T474M on NM_004824.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 32/223 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as rs746598692; called by muse, mutect2, varscan2
- CDYL2 | c.916G>A p.V306M | Missense Mutation (SNP) | VAF 9/45 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs778486733, COSV73654435; called by muse, mutect2, varscan2
- CEACAM4 | c.442C>T p.L148F | Missense Mutation (SNP) | VAF 7/44 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.55); catalogued as rs1555801677; called by muse, mutect2, varscan2
- CEACAM5 | c.524C>T p.T175I | Missense Mutation (SNP) | VAF 40/177 reads (23%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.997); catalogued as rs1555814650; called by muse, mutect2, varscan2
- CELA2A | c.469G>A p.V157I | Missense Mutation (SNP) | VAF 19/114 reads (17%) | SIFT tolerated (0.71); PolyPhen possibly damaging (0.505); catalogued as rs199836994; called by muse, mutect2, varscan2
- CELA3B | c.488G>A p.G163D | Missense Mutation (SNP) | VAF 10/52 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1158940493, COSV100448630; called by mutect2, varscan2
- CELF6 | c.301C>A p.L101I | Missense Mutation (SNP) | VAF 32/134 reads (24%) | SIFT tolerated (0.33); PolyPhen benign (0.078); catalogued as rs1271970169; called by muse, mutect2, varscan2
- CELSR1 | c.1750G>A p.V584M | Missense Mutation (SNP) | VAF 11/55 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV53099743; called by muse, mutect2, varscan2
- CELSR2 | c.2525G>A p.R842H | Missense Mutation (SNP) | VAF 15/79 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs1310874903, COSV54769414; called by muse, mutect2, varscan2
- CELSR2 | c.6079T>C p.S2027P | Missense Mutation (SNP) | VAF 59/302 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.925); catalogued as COSV99604320; called by muse, mutect2, varscan2
- CEMIP | c.925G>A p.E309K | Missense Mutation (SNP) | VAF 48/223 reads (22%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.917); catalogued as rs759087523; called by muse, mutect2, varscan2
- CENPC | c.1357G>A p.E453K | Missense Mutation (SNP) | VAF 38/221 reads (17%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV56622895; called by muse, mutect2, varscan2
- CENPI | c.497G>A p.R166H | Missense Mutation (SNP) | VAF 63/555 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as rs137937705, COSV54500472; ClinVar: uncertain significance; called by muse, varscan2
- CENPO | c.748G>A p.V250I | Missense Mutation (SNP) | VAF 28/130 reads (22%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.923); catalogued as rs769211623, COSV53170042; called by muse, mutect2, varscan2
- CEP135 | c.1408C>T p.R470* | Nonsense Mutation (SNP) | VAF 20/108 reads (19%) | catalogued as rs138291324; called by muse, mutect2, varscan2
- CEP152 | c.3725C>T p.P1242L (on ENST00000380950 / NM_001194998.2; = p.P1186L on NM_014985.4) | Missense Mutation (SNP) | VAF 83/383 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs370372775; called by muse, mutect2, varscan2
- CEP152 | c.1204G>A p.V402M | Missense Mutation (SNP) | VAF 28/190 reads (15%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.961); catalogued as rs780764155, COSV57860338; called by muse, mutect2, varscan2
- CEP170 | c.3766C>T p.R1256C | Missense Mutation (SNP) | VAF 46/249 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1326079942; called by muse, mutect2, varscan2
- CEP170B | c.2354G>T p.R785L (on ENST00000453495; = p.R714L on NM_015005.3) | Missense Mutation (SNP) | VAF 7/23 reads (30%) | SIFT tolerated (0.15); PolyPhen benign (0.232); catalogued as COSV69026399; called by muse, varscan2
- CEP192 | c.6356C>T p.P2119L | Missense Mutation (SNP) | VAF 31/172 reads (18%) | SIFT tolerated (0.31); PolyPhen benign (0.026); catalogued as rs146842672; called by muse, mutect2, varscan2
- CEP250 | c.4321C>T p.R1441W | Missense Mutation (SNP) | VAF 11/55 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.719); catalogued as rs533821058; called by muse, mutect2, varscan2
- CEP350 | c.9032G>A p.R3011Q | Missense Mutation (SNP) | VAF 49/229 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.846); catalogued as rs761674978; called by muse, mutect2, varscan2
- CEP41 | c.785C>T p.P262L | Missense Mutation (SNP) | VAF 24/149 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs200709703; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CEP63 | c.479G>A p.R160H | Missense Mutation (SNP) | VAF 18/83 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as rs202055421, COSV59675935; called by muse, mutect2, varscan2
- CEP72 | c.1162G>A p.E388K | Missense Mutation (SNP) | VAF 7/38 reads (18%) | SIFT tolerated (0.44); PolyPhen benign (0.014); catalogued as rs267600673; called by muse, mutect2, varscan2
- CEP85 | c.553G>T p.E185* | Nonsense Mutation (SNP) | VAF 12/70 reads (17%) | catalogued as COSV53331624; called by muse, mutect2, varscan2
- CERS3 | c.700G>A p.V234M | Missense Mutation (SNP) | VAF 10/61 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); catalogued as rs373080717, COSV52565917; called by muse, mutect2, varscan2
- CERT1 | c.1118C>T p.A373V (on ENST00000405807 / NM_001130105.1; = p.A245V on NM_005713.3) | Missense Mutation (SNP) | VAF 53/299 reads (18%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV99783571; called by muse, mutect2, varscan2
- CES1 | c.1141C>A p.L381I (on ENST00000361503 / NM_001025194.2; = p.L380I on NM_001266.5) | Missense Mutation (SNP) | VAF 10/78 reads (13%) | SIFT tolerated (0.18); PolyPhen benign (0.102); catalogued as COSV62085901; called by muse, mutect2, varscan2
- CES5A | c.1531G>T p.A511S (on ENST00000290567 / NM_001143685.2; = p.A461S on NM_145024.3) | Missense Mutation (SNP) | VAF 24/116 reads (21%) | SIFT tolerated (0.5); PolyPhen possibly damaging (0.735); catalogued as rs760544900; called by muse, mutect2, varscan2
- CFAP251 | c.1627G>A p.A543T | Missense Mutation (SNP) | VAF 49/260 reads (19%) | SIFT tolerated (0.07); PolyPhen benign (0.012); catalogued as rs778957006; called by muse, mutect2, varscan2
- CFAP298-TCP10L | c.172C>A p.L58I | Missense Mutation (SNP) | VAF 84/466 reads (18%) | SIFT tolerated, low confidence (0.23); PolyPhen possibly damaging (0.816); catalogued as COSV99267652; called by muse, mutect2, varscan2
- CFAP44 | c.2725G>T p.E909* | Nonsense Mutation (SNP) | VAF 46/174 reads (26%) | catalogued as COSV55613566; called by muse, mutect2, varscan2
- CFAP45 | c.1556G>T p.R519M | Missense Mutation (SNP) | VAF 22/127 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.452); catalogued as COSV63650294; called by muse, mutect2, varscan2
- CFAP53 | c.1086A>T p.R362S | Missense Mutation (SNP) | VAF 66/359 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.328); catalogued as rs775661778; called by muse, mutect2, varscan2
- CFAP53 | c.530G>A p.C177Y | Missense Mutation (SNP) | VAF 15/318 reads (5%) | SIFT deleterious (0.02); PolyPhen benign (0.276); catalogued as rs1056143543; called by muse, mutect2
- CFAP54 | c.6326G>T p.R2109I | Missense Mutation (SNP) | VAF 32/204 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.78); catalogued as COSV61571753; called by muse, varscan2
- CFAP58 | c.1988G>A p.R663H | Missense Mutation (SNP) | VAF 12/81 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.962); catalogued as rs749117192, COSV63833479; called by muse, mutect2, varscan2
- CFAP58 | c.2472G>T p.K824N | Missense Mutation (SNP) | VAF 13/105 reads (12%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.661); catalogued as COSV63835417; called by muse, mutect2, varscan2
- CFAP61 | c.50G>A p.R17Q | Missense Mutation (SNP) | VAF 79/371 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs760800263, COSV55622175; called by muse, mutect2, varscan2
- CFAP61 | c.2251G>T p.A751S | Missense Mutation (SNP) | VAF 17/92 reads (18%) | SIFT tolerated (0.42); PolyPhen benign (0.203); catalogued as COSV55649771; called by muse, mutect2, varscan2
- CFAP74 | c.1537C>T p.R513C | Missense Mutation (SNP) | VAF 16/49 reads (33%) | SIFT tolerated (0.15); PolyPhen benign (0.018); catalogued as rs766114699, COSV54568567; called by muse, mutect2, varscan2
- CFAP77 | c.848G>A p.R283H | Missense Mutation (SNP) | VAF 14/43 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.34); catalogued as rs765507051, COSV58011972; called by muse, mutect2, varscan2
- CFAP92 | c.1129G>A p.A377T | Missense Mutation (SNP) | VAF 51/288 reads (18%) | SIFT tolerated (0.57); PolyPhen benign (0.021); catalogued as rs373502745, COSV104369951; called by muse, mutect2, varscan2
- CFC1 | c.139C>T p.R47* | Nonsense Mutation (SNP) | VAF 55/517 reads (11%) | catalogued as rs773029689; called by muse, mutect2, varscan2
- CFH | c.158G>A p.R53H | Missense Mutation (SNP) | VAF 21/124 reads (17%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.991); catalogued as rs976333015, CM070669, COSV62776065; called by muse, mutect2, varscan2
- CFHR2 | c.394C>T p.R132W | Missense Mutation (SNP) | VAF 50/210 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.965); catalogued as rs111586074, COSV66381906; called by muse, mutect2, varscan2
- CFHR4 | c.1007A>C p.K336T (on ENST00000367416 / NM_001201551.2; = p.K90T on NM_006684.5) | Missense Mutation (SNP) | VAF 15/95 reads (16%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.76); catalogued as rs780312410; called by muse, mutect2, varscan2
- CFP | c.1025G>A p.G342D | Missense Mutation (SNP) | VAF 13/88 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55951037; called by muse, varscan2
- CGNL1 | c.2012G>A p.R671Q | Missense Mutation (SNP) | VAF 21/115 reads (18%) | SIFT tolerated (0.48); PolyPhen benign (0.007); catalogued as rs772369065; called by muse, mutect2, varscan2
- CGNL1 | c.3671G>A p.R1224K | Missense Mutation (SNP) | VAF 13/46 reads (28%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.976); catalogued as rs768867429; called by muse, varscan2
- CHAD | c.937C>T p.R313W | Missense Mutation (SNP) | VAF 39/185 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.551); catalogued as rs756610333; called by muse, mutect2, varscan2
- CHAD | c.290G>A p.G97D | Missense Mutation (SNP) | VAF 17/93 reads (18%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as rs1302386506, COSV51972362; called by muse, mutect2, varscan2
- CHAF1A | c.1028G>A p.R343H | Missense Mutation (SNP) | VAF 55/208 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.799); catalogued as rs758651234; called by muse, mutect2, varscan2
- CHAF1A | c.1624C>T p.R542C | Missense Mutation (SNP) | VAF 31/185 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.921); catalogued as rs927478629; called by muse, mutect2, varscan2
- CHCHD10 | c.381G>T p.E127D | Missense Mutation (SNP) | VAF 9/52 reads (17%) | SIFT tolerated (0.07); PolyPhen benign (0.048); catalogued as rs1456060216; called by muse, mutect2, varscan2
- CHD4 | c.2399G>A p.R800H (on ENST00000357008 / NM_001363606.2; = p.R813H on NM_001273.5) | Missense Mutation (SNP) | VAF 29/145 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV58908829; called by muse, mutect2, varscan2
- CHD5 | c.4352G>A p.W1451* | Nonsense Mutation (SNP) | VAF 10/65 reads (15%) | catalogued as COSV99314837; called by muse, mutect2, varscan2
- CHD6 | c.2512C>T p.R838C | Missense Mutation (SNP) | VAF 6/46 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV58561363; called by muse, mutect2, varscan2
- CHFR | c.1075G>A p.V359M (on ENST00000432561 / NM_001161345.1; = p.V318M on NM_018223.2) | Missense Mutation (SNP) | VAF 38/221 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs775898959; called by muse, mutect2, varscan2
- CHGA | c.874G>A p.E292K | Missense Mutation (SNP) | VAF 11/56 reads (20%) | SIFT tolerated (0.26); PolyPhen benign (0.012); catalogued as rs371137176; called by muse, mutect2, varscan2
- CHKA | c.685G>A p.A229T | Missense Mutation (SNP) | VAF 46/206 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1186013179; called by muse, mutect2, varscan2
- CHRDL2 | c.1054C>T p.R352C | Missense Mutation (SNP) | VAF 17/101 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.77); catalogued as rs376221805; called by muse, mutect2, varscan2
- CHRM1 | c.772C>T p.R258C | Missense Mutation (SNP) | VAF 5/21 reads (24%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.696); catalogued as rs777333908; called by muse, varscan2
- CHRM4 | c.29G>T p.S10I | Missense Mutation (SNP) | VAF 18/82 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.006); catalogued as COSV63127559; called by muse, varscan2
- CHRNE | c.835G>A p.V279I | Missense Mutation (SNP) | VAF 48/232 reads (21%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.997); catalogued as CM057541, CM094125; called by muse, mutect2, varscan2
- CHST4 | c.623G>A p.R208Q | Missense Mutation (SNP) | VAF 12/58 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs748043139, COSV100632883; called by muse, mutect2, varscan2
- CHST7 | c.505C>T p.R169W | Missense Mutation (SNP) | VAF 5/36 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.713); catalogued as COSV99333053; called by muse, mutect2, varscan2
- CHST8 | c.1154C>T p.A385V | Missense Mutation (SNP) | VAF 10/55 reads (18%) | SIFT tolerated (0.16); PolyPhen benign (0.027); catalogued as COSV52859177; called by muse, mutect2
- CHSY1 | c.1502C>A p.S501Y | Missense Mutation (SNP) | VAF 25/148 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.747); catalogued as COSV54252212; called by muse, mutect2, varscan2
- CHTF18 | c.1156G>A p.V386M | Missense Mutation (SNP) | VAF 22/92 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1299409975, COSV50102729; called by muse, mutect2, varscan2
- CIAPIN1 | c.512C>A p.S171Y | Missense Mutation (SNP) | VAF 47/258 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.871); catalogued as COSV67953605; called by muse, mutect2, varscan2
- CIBAR1 | c.400C>T p.R134C | Missense Mutation (SNP) | VAF 96/497 reads (19%) | SIFT tolerated (0.05); PolyPhen benign (0.262); catalogued as rs1215667615; called by muse, mutect2, varscan2
- CIDEC | c.68G>A p.R23H | Missense Mutation (SNP) | VAF 5/36 reads (14%) | SIFT deleterious (0.04); PolyPhen benign (0.057); catalogued as rs1187496161; called by muse, mutect2, varscan2
- CKAP2 | c.1879C>T p.R627C (on ENST00000378037 / NM_001098525.2; = p.R626C on NM_018204.5) | Missense Mutation (SNP) | VAF 56/248 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as rs748867286, COSV51623279; called by muse, mutect2
- CKAP2L | c.1190G>T p.R397I | Missense Mutation (SNP) | VAF 105/570 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.428); catalogued as COSV56695633; called by muse, mutect2, varscan2
- CKAP4 | c.1450G>A p.G484S | Missense Mutation (SNP) | VAF 6/23 reads (26%) | SIFT tolerated (0.81); PolyPhen benign (0.001); catalogued as rs771014402; called by muse, mutect2, varscan2
- CLCA4 | c.292C>T p.H98Y | Missense Mutation (SNP) | VAF 66/362 reads (18%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99760619; called by muse, varscan2
- CLCA4 | c.691C>T p.Q231* | Nonsense Mutation (SNP) | VAF 16/99 reads (16%) | catalogued as rs78872817; called by muse, varscan2
- CLCA4 | c.926T>A p.L309* | Nonsense Mutation (SNP) | VAF 24/145 reads (17%) | catalogued as COSV55366513; called by muse, mutect2, varscan2
- CLCN2 | c.2506C>T p.R836W | Missense Mutation (SNP) | VAF 17/104 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1321914283; called by muse, mutect2, varscan2
- CLCN5 | c.282C>A p.F94L | Missense Mutation (SNP) | VAF 37/215 reads (17%) | SIFT tolerated (0.22); PolyPhen benign (0.049); catalogued as COSV100259944; called by muse, mutect2, varscan2
- CLCN6 | c.2294C>T p.S765L | Missense Mutation (SNP) | VAF 12/49 reads (24%) | SIFT tolerated (0.46); PolyPhen benign (0.011); catalogued as rs752502680, COSV56738059; called by muse, mutect2, varscan2
- CLCNKA | c.747A>G p.I249M | Missense Mutation (SNP) | VAF 27/123 reads (22%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs201977074; called by muse, mutect2, varscan2
- CLCNKB | c.95T>C p.I32T | Missense Mutation (SNP) | VAF 26/118 reads (22%) | SIFT tolerated (0.07); PolyPhen benign (0.092); catalogued as rs1431164824; called by muse, mutect2, varscan2
- CLDN25 | c.124G>A p.E42K | Missense Mutation (SNP) | VAF 16/87 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.916); catalogued as rs371879188; called by muse, varscan2
- CLDN25 | c.170G>A p.R57Q | Missense Mutation (SNP) | VAF 18/88 reads (20%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs371445026; called by muse, varscan2
- CLEC3A | c.352G>A p.D118N (on ENST00000651443; = p.D109N on NM_005752.6) | Missense Mutation (SNP) | VAF 9/63 reads (14%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.681); catalogued as COSV55222580; called by muse, mutect2, varscan2
- CLIP4 | c.12G>T p.E4D | Missense Mutation (SNP) | VAF 132/694 reads (19%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.978); catalogued as rs780926460; called by muse, mutect2, varscan2
- CLK1 | c.818G>A p.C273Y | Missense Mutation (SNP) | VAF 27/147 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV58432601; called by muse, mutect2, varscan2
- CLK1 | c.200A>G p.Y67C | Missense Mutation (SNP) | VAF 48/287 reads (17%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.502); catalogued as rs200483830; called by muse, mutect2, varscan2
- CLN3 | c.887G>A p.R296H (on ENST00000360019 / NM_001286104.2; = p.R320H on NM_000086.2) | Missense Mutation (SNP) | VAF 9/45 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs138636923; called by muse, mutect2, varscan2
- CLPSL1 | c.260G>A p.R87Q | Missense Mutation (SNP) | VAF 52/476 reads (11%) | SIFT tolerated (0.4); PolyPhen benign (0); catalogued as rs746478457; called by muse, mutect2, varscan2
- CLSTN1 | c.2457G>A p.M819I (on ENST00000377298 / NM_001009566.3; = p.M809I on NM_014944.4) | Missense Mutation (SNP) | VAF 33/196 reads (17%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as rs1447153753; called by muse, mutect2, varscan2
- CLSTN1 | c.1999G>T p.A667S (on ENST00000377298 / NM_001009566.3; = p.A657S on NM_014944.4) | Missense Mutation (SNP) | VAF 22/94 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.993); catalogued as rs1476544726; called by muse, mutect2, varscan2
- CLTC | c.187C>T p.R63* | Nonsense Mutation (SNP) | VAF 30/162 reads (19%) | catalogued as COSV99291998; called by muse, mutect2, varscan2
- CLYBL | c.727C>A p.L243M | Missense Mutation (SNP) | VAF 18/75 reads (24%) | SIFT tolerated (0.39); PolyPhen possibly damaging (0.45); catalogued as COSV59228064; called by muse, mutect2, varscan2
- CMTM2 | c.470G>A p.C157Y | Missense Mutation (SNP) | VAF 72/272 reads (26%) | SIFT deleterious (0.04); PolyPhen benign (0.116); catalogued as rs1367508221, COSV51749374; called by muse, mutect2, varscan2
- CNBD2 | c.472C>A p.L158M | Missense Mutation (SNP) | VAF 30/149 reads (20%) | SIFT tolerated (0.15); PolyPhen benign (0.232); catalogued as COSV100839036; called by muse, mutect2, varscan2
- CNDP2 | c.1033G>A p.V345M | Missense Mutation (SNP) | VAF 11/69 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs375477095; called by muse, mutect2, varscan2
- CNGA2 | c.635G>T p.R212L | Missense Mutation (SNP) | VAF 9/57 reads (16%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.592); catalogued as COSV61705552; called by mutect2, varscan2
- CNGA4 | c.866A>G p.Y289C | Missense Mutation (SNP) | VAF 6/48 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV66005725; called by muse, mutect2
- CNGB3 | c.2344C>A p.Q782K | Missense Mutation (SNP) | VAF 60/333 reads (18%) | SIFT tolerated (0.26); PolyPhen benign (0.039); catalogued as COSV60684853; called by muse, mutect2, varscan2
- CNIH3 | c.70G>A p.A24T | Missense Mutation (SNP) | VAF 83/454 reads (18%) | SIFT tolerated (0.19); PolyPhen benign (0.146); catalogued as rs893683657, COSV55274461; called by muse, mutect2, varscan2
- CNKSR3 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 25/116 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.827); catalogued as rs1339331029; called by muse, mutect2, varscan2
- CNNM1 | c.1906C>T p.R636W | Missense Mutation (SNP) | VAF 11/43 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as rs747571350; called by muse, mutect2, varscan2
- CNOT1 | c.1604G>A p.R535H | Missense Mutation (SNP) | VAF 43/219 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.869); catalogued as COSV57765855; called by muse, mutect2, varscan2
- CNTN6 | c.1069C>T p.R357* | Nonsense Mutation (SNP) | VAF 6/50 reads (12%) | catalogued as rs749841767; called by mutect2, varscan2
- CNTN6 | c.1627G>A p.D543N | Missense Mutation (SNP) | VAF 33/200 reads (17%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.999); catalogued as rs376637146; called by muse, mutect2, varscan2
- CNTN6 | c.2053G>T p.E685* | Nonsense Mutation (SNP) | VAF 18/123 reads (15%) | catalogued as COSV100611765; called by muse, mutect2, varscan2
- CNTNAP2 | c.361G>T p.G121W | Missense Mutation (SNP) | VAF 45/247 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV62148735; called by muse, varscan2
- CNTNAP2 | c.770G>A p.G257D | Missense Mutation (SNP) | VAF 15/69 reads (22%) | SIFT tolerated (0.38); PolyPhen possibly damaging (0.873); catalogued as rs1291241094, COSV62232552; called by muse, mutect2, varscan2
- CNTNAP3 | c.3262C>T p.P1088S | Missense Mutation (SNP) | VAF 79/357 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.023); catalogued as rs267602246; called by muse, mutect2, varscan2
- CNTNAP5 | c.41T>C p.L14P | Missense Mutation (SNP) | VAF 61/380 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.548); catalogued as COSV70492349; called by muse, varscan2
- CNTROB | c.2651G>A p.R884Q | Missense Mutation (SNP) | VAF 20/101 reads (20%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.695); catalogued as rs371383062; called by muse, mutect2, varscan2
- COL10A1 | c.934C>T p.P312S | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT tolerated (0.48); PolyPhen benign (0.091); catalogued as rs1358299038; called by muse, mutect2, varscan2
- COL10A1 | c.262C>T p.P88S | Missense Mutation (SNP) | VAF 12/58 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.767); catalogued as rs1438351587, COSV104387946; called by muse, mutect2, varscan2
- COL11A1 | c.4624G>T p.V1542F | Missense Mutation (SNP) | VAF 45/210 reads (21%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.999); catalogued as COSV62178148; called by muse, varscan2
- COL11A1 | c.2018G>C p.G673A | Missense Mutation (SNP) | VAF 22/105 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs765120248; called by muse, mutect2, varscan2
- COL16A1 | c.4672G>T p.G1558C | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99057263; called by muse, varscan2
- COL16A1 | c.3211C>T p.R1071* | Nonsense Mutation (SNP) | VAF 40/247 reads (16%) | catalogued as rs368967625; called by muse, mutect2, varscan2
- COL16A1 | c.1841G>C p.G614A | Missense Mutation (SNP) | VAF 28/160 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54706458; called by muse, varscan2
- COL18A1 | c.607G>A p.A203T | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0.009); catalogued as COSV62703549; called by mutect2, varscan2
- COL20A1 | c.1336G>A p.V446M | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs775264398, COSV58911667; called by mutect2, varscan2
- COL22A1 | c.2311G>T p.G771* | Nonsense Mutation (SNP) | VAF 36/144 reads (25%) | catalogued as rs1475630600; called by muse, varscan2
- COL22A1 | c.1947+1G>A p.X649_splice | Splice Site (SNP) | VAF 21/100 reads (21%) | catalogued as rs765811436; called by muse, mutect2, varscan2
- COL25A1 | c.1322G>T p.R441M | Missense Mutation (SNP) | VAF 35/194 reads (18%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.52); catalogued as rs201342548; called by muse, mutect2, varscan2
- COL4A2 | c.1957G>A p.A653T | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT tolerated (0.08); PolyPhen benign (0.022); catalogued as rs199875726; called by mutect2, varscan2
- COL4A5 | c.1180G>A p.G394S | Missense Mutation (SNP) | VAF 14/85 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.894); catalogued as COSV60372475; called by muse, mutect2, varscan2
- COL4A5 | c.4718T>C p.V1573A | Missense Mutation (SNP) | VAF 14/106 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.923); catalogued as COSV60368418, COSV60368531; called by muse, mutect2, varscan2
- COL4A6 | c.286C>T p.P96S | Missense Mutation (SNP) | VAF 12/74 reads (16%) | SIFT tolerated (0.35); PolyPhen benign (0.234); catalogued as rs928894320; called by muse, mutect2, varscan2
- COL5A1 | c.466C>T p.R156W | Missense Mutation (SNP) | VAF 21/55 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as rs760354881, CD050439; called by muse, mutect2, varscan2
- COL5A2 | c.2104G>A p.G702R | Missense Mutation (SNP) | VAF 14/82 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs772811492, COSV66407304; ClinVar: uncertain significance; called by muse, varscan2
- COL6A3 | c.4561G>A p.E1521K | Missense Mutation (SNP) | VAF 20/96 reads (21%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.59); catalogued as rs113538665, COSV55107615; called by muse, varscan2
- COL6A6 | c.3112C>T p.R1038* | Nonsense Mutation (SNP) | VAF 35/145 reads (24%) | catalogued as rs777444690, COSV62018197; called by muse, mutect2, varscan2
- COL7A1 | c.5830C>T p.R1944W | Missense Mutation (SNP) | VAF 24/227 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as rs527416146, COSV60406432; called by muse, mutect2, varscan2
- COL7A1 | c.4973G>A p.G1658D | Missense Mutation (SNP) | VAF 27/125 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs780594226; called by muse, mutect2, varscan2
- COL8A2 | c.1974G>T p.Q658H | Missense Mutation (SNP) | VAF 11/44 reads (25%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.815); catalogued as COSV57443633; called by muse, mutect2, varscan2
- COLGALT2 | c.958C>T p.R320C | Missense Mutation (SNP) | VAF 11/76 reads (14%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as rs181809768; called by mutect2, varscan2
- COPB1 | c.2788C>T p.R930C | Missense Mutation (SNP) | VAF 21/141 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1182148424, COSV51448599, COSV99999434; called by muse, mutect2, varscan2
- COPZ1 | c.126G>T p.K42N | Missense Mutation (SNP) | VAF 35/175 reads (20%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.863); catalogued as COSV50432942; called by muse, mutect2, varscan2
- COQ4 | c.374G>A p.R125H | Missense Mutation (SNP) | VAF 12/82 reads (15%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.766); catalogued as rs752897625; called by muse, mutect2, varscan2
- COQ6 | c.764G>T p.G255V | Missense Mutation (SNP) | VAF 30/207 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53178156; called by muse, mutect2, varscan2
- COQ8A | c.221G>T p.G74V | Missense Mutation (SNP) | VAF 16/86 reads (19%) | SIFT tolerated, low confidence (0.5); PolyPhen benign (0.046); catalogued as COSV64657123; called by muse, mutect2, varscan2
- COQ9 | c.697G>T p.D233Y | Missense Mutation (SNP) | VAF 17/74 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99346015; called by muse, mutect2, varscan2
- CPA4 | c.806G>A p.S269N | Missense Mutation (SNP) | VAF 11/35 reads (31%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.585); catalogued as COSV55984700; called by muse, mutect2, varscan2
- CPE | c.902G>A p.R301H | Missense Mutation (SNP) | VAF 22/97 reads (23%) | SIFT tolerated (0.49); PolyPhen probably damaging (0.941); catalogued as rs141250110; called by muse, mutect2, varscan2
- CPNE4 | c.647C>A p.S216Y | Missense Mutation (SNP) | VAF 16/95 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.918); catalogued as COSV70192770, COSV70201760; called by muse, mutect2, varscan2
- CPNE7 | c.551C>T p.T184M | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT tolerated (0.27); PolyPhen benign (0.005); catalogued as rs200477040; called by muse, mutect2, varscan2
- CPNE7 | c.1258G>A p.V420M | Missense Mutation (SNP) | VAF 16/130 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs200220806; called by muse, mutect2, varscan2
- CPSF2 | c.1736G>A p.R579H | Missense Mutation (SNP) | VAF 13/103 reads (13%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as rs1160049761, COSV100102722; called by muse, mutect2, varscan2
- CPT1B | c.539G>A p.R180K | Missense Mutation (SNP) | VAF 25/160 reads (16%) | SIFT tolerated (0.21); PolyPhen benign (0.001); catalogued as rs1184552350, COSV100376862; called by muse, varscan2
- CPTP | c.463C>T p.R155C | Missense Mutation (SNP) | VAF 8/18 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs375729538, COSV59562612; called by muse, mutect2, varscan2
- CPXM1 | c.1294G>A p.D432N | Missense Mutation (SNP) | VAF 22/118 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV66045245; called by muse, mutect2, varscan2
- CPZ | c.1069-1G>A p.X357_splice (on ENST00000360986 / NM_001014447.3; = p.X346_splice on NM_003652.3) | Splice Site (SNP) | VAF 23/104 reads (22%) | catalogued as rs372440409; called by muse, varscan2
- CPZ | c.1222G>A p.E408K (on ENST00000360986 / NM_001014447.3; = p.E397K on NM_003652.3) | Missense Mutation (SNP) | VAF 17/86 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.756); catalogued as rs558061091; called by muse, varscan2
- CR1 | c.3752C>T p.P1251L | Missense Mutation (SNP) | VAF 14/95 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs368172549; called by muse, mutect2, varscan2
- CR2 | c.980T>C p.V327A | Missense Mutation (SNP) | VAF 23/112 reads (21%) | SIFT tolerated (0.5); PolyPhen benign (0.006); catalogued as rs778207648, COSV65508291; called by muse, mutect2, varscan2
- CRACD | c.2789C>A p.P930H | Missense Mutation (SNP) | VAF 14/70 reads (20%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.874); catalogued as COSV99950090; called by muse, mutect2, varscan2
- CRACD | c.3493C>T p.R1165C | Missense Mutation (SNP) | VAF 13/46 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs747217847; called by muse, mutect2, varscan2
- CRACR2B | c.306G>T p.Q102H | Missense Mutation (SNP) | VAF 9/47 reads (19%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.465); catalogued as COSV58990812; called by muse, mutect2, varscan2
- CREB5 | c.1172G>A p.R391H (on ENST00000357727 / NM_182898.4; = p.R384H on NM_004904.3) | Missense Mutation (SNP) | VAF 10/73 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63217985, COSV63227292; called by muse, mutect2, varscan2
- CREBBP | c.5642G>A p.S1881N | Missense Mutation (SNP) | VAF 26/127 reads (20%) | SIFT tolerated (0.16); PolyPhen benign (0.264); catalogued as rs1406476257; called by muse, mutect2, varscan2
- CRISP3 | c.478C>T p.P160S (on ENST00000371159 / NM_001368123.1; = p.P142S on NM_006061.4) | Missense Mutation (SNP) | VAF 29/162 reads (18%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.495); catalogued as COSV99538843; called by muse, mutect2, varscan2
- CRISPLD1 | c.781C>T p.R261* | Nonsense Mutation (SNP) | VAF 27/140 reads (19%) | catalogued as rs891363871, COSV51545699; called by muse, mutect2, varscan2
- CRLF3 | c.421G>A p.D141N | Missense Mutation (SNP) | VAF 53/253 reads (21%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.586); catalogued as rs1026034483; called by muse, mutect2, varscan2
- CRNKL1 | c.820C>T p.R274* | Nonsense Mutation (SNP) | VAF 71/349 reads (20%) | catalogued as rs199698864; called by muse, mutect2, varscan2
- CROCC | c.199C>A p.L67M | Missense Mutation (SNP) | VAF 4/33 reads (12%) | SIFT tolerated (0.26); PolyPhen benign (0.24); catalogued as COSV65014862; called by mutect2, varscan2
- CRTAC1 | c.439G>A p.D147N | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.96); catalogued as rs1233124549; called by muse, mutect2, varscan2
- CRY2 | c.934C>T p.R312* | Nonsense Mutation (SNP) | VAF 12/65 reads (18%) | catalogued as rs1429024008; called by muse, mutect2, varscan2
- CRYAB | c.511G>A p.A171T | Missense Mutation (SNP) | VAF 31/171 reads (18%) | SIFT tolerated (0.12); PolyPhen benign (0.014); catalogued as rs370803064, CM082584, COSV57052494; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CSF2RA | c.131C>T p.T44M | Missense Mutation (SNP) | VAF 75/386 reads (19%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.858); catalogued as rs746211899, COSV62624209; called by muse, varscan2
- CSKMT | c.613C>T p.R205* | Nonsense Mutation (SNP) | VAF 23/84 reads (27%) | catalogued as rs778729080, COSV100648995; called by muse, mutect2, varscan2
- CSMD1 | c.10642G>T p.E3548* (on ENST00000520002; = p.E3547* on NM_033225.6) | Nonsense Mutation (SNP) | VAF 55/304 reads (18%) | catalogued as rs1197804700; called by muse, varscan2
- CSMD1 | c.8741C>T p.T2914I (on ENST00000520002; = p.T2913I on NM_033225.6) | Missense Mutation (SNP) | VAF 6/27 reads (22%) | SIFT tolerated (0.06); PolyPhen benign (0.042); catalogued as rs760750981; called by mutect2, varscan2
- CSMD1 | c.8205C>T p.V2735= (on ENST00000520002; = p.V2734= on NM_033225.6) | Splice Region (SNP) | VAF 5/28 reads (18%) | catalogued as COSV59285822; called by muse, mutect2, varscan2
- CSMD2 | c.8017C>A p.L2673M | Missense Mutation (SNP) | VAF 10/54 reads (19%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.461); catalogued as COSV53951708; called by muse, mutect2, varscan2
- CSMD2 | c.2632C>T p.R878C | Missense Mutation (SNP) | VAF 11/55 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53971764; called by muse, mutect2, varscan2
- CSMD3 | c.7939G>T p.D2647Y (on ENST00000297405 / NM_001363185.1; = p.D2543Y on NM_052900.3) | Missense Mutation (SNP) | VAF 28/133 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV99819929; called by muse, mutect2, varscan2
- CSMD3 | c.7375A>G p.N2459D (on ENST00000297405 / NM_001363185.1; = p.N2355D on NM_052900.3) | Missense Mutation (SNP) | VAF 14/108 reads (13%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.489); catalogued as COSV99822829; called by muse, mutect2, varscan2
- CSMD3 | c.3734C>T p.A1245V (on ENST00000297405 / NM_001363185.1; = p.A1141V on NM_052900.3) | Missense Mutation (SNP) | VAF 26/154 reads (17%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as COSV52269281, COSV99842985; called by muse, mutect2, varscan2
- CSMD3 | c.3269C>A p.S1090Y (on ENST00000297405 / NM_001363185.1; = p.S986Y on NM_052900.3) | Missense Mutation (SNP) | VAF 65/298 reads (22%) | SIFT deleterious (0.04); PolyPhen benign (0.044); catalogued as COSV52100273, COSV99838518; called by muse, mutect2, varscan2
- CSMD3 | c.3062G>A p.R1021H (on ENST00000297405 / NM_001363185.1; = p.R917H on NM_052900.3) | Missense Mutation (SNP) | VAF 31/146 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV52246281; called by muse, mutect2, varscan2
- CSMD3 | c.2047C>T p.R683C (on ENST00000297405 / NM_001363185.1; = p.R579C on NM_052900.3) | Missense Mutation (SNP) | VAF 32/163 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.901); catalogued as rs1266203286, COSV52185681; called by muse, mutect2, varscan2
- CSMD3 | c.545G>T p.G182V | Missense Mutation (SNP) | VAF 15/62 reads (24%) | SIFT tolerated (0.05); PolyPhen benign (0.003); catalogued as rs541690240; called by muse, mutect2, varscan2
- CSNK1A1 | c.728C>T p.T243M | Missense Mutation (SNP) | VAF 86/422 reads (20%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.733); catalogued as rs1331516795; called by muse, mutect2, varscan2
- CSNK1A1L | c.896C>T p.T299M | Missense Mutation (SNP) | VAF 135/697 reads (19%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.908); catalogued as rs747425670; called by muse, mutect2, varscan2
- CSNK1E | c.808C>T p.R270C | Missense Mutation (SNP) | VAF 50/265 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); catalogued as rs775283367, COSV63291416; called by muse, mutect2, varscan2
- CSNK1E | c.640C>T p.Q214* | Nonsense Mutation (SNP) | VAF 44/217 reads (20%) | catalogued as rs1555907769; called by muse, varscan2
- CSNK1G3 | c.155G>A p.G52D | Missense Mutation (SNP) | VAF 17/103 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV62056698; called by muse, mutect2, varscan2
- CSNK2A1 | c.838C>T p.R280* | Nonsense Mutation (SNP) | VAF 12/55 reads (22%) | catalogued as COSV53935771; called by muse, mutect2, varscan2
- CSNK2A2 | c.887C>T p.P296L | Missense Mutation (SNP) | VAF 29/163 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.083); catalogued as rs759457020; called by muse, mutect2, varscan2
- CSPP1 | c.1391A>T p.K464I (on ENST00000676605; = p.K423I on NM_024790.6) | Missense Mutation (SNP) | VAF 12/66 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs1231591915; called by muse, mutect2, varscan2
- CSRNP2 | c.547C>T p.R183* | Nonsense Mutation (SNP) | VAF 32/124 reads (26%) | catalogued as rs1206289307, COSV57333911; called by mutect2, varscan2
- CSRNP3 | c.911C>A p.P304H | Missense Mutation (SNP) | VAF 8/54 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.176); catalogued as COSV58787743; called by muse, mutect2, varscan2
- CST11 | c.206G>A p.R69Q | Missense Mutation (SNP) | VAF 7/64 reads (11%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.999); catalogued as rs140128807, COSV104424721; called by mutect2, varscan2
- CSTF2T | c.710C>T p.P237L | Missense Mutation (SNP) | VAF 9/42 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.587); catalogued as rs138223207; called by mutect2, varscan2
- CSTF3 | c.2020G>A p.V674M | Missense Mutation (SNP) | VAF 26/157 reads (17%) | SIFT tolerated (0.26); PolyPhen benign (0.022); catalogued as rs757337076; called by muse, mutect2, varscan2
- CT55 | c.518G>T p.R173L | Missense Mutation (SNP) | VAF 31/187 reads (17%) | SIFT deleterious (0.03); PolyPhen benign (0.06); catalogued as COSV99358886; called by muse, mutect2, varscan2
- CTBS | c.283G>A p.A95T | Missense Mutation (SNP) | VAF 70/356 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs374699739; called by muse, mutect2, varscan2
- CTC1 | c.3154C>T p.Q1052* | Nonsense Mutation (SNP) | VAF 23/115 reads (20%) | catalogued as rs1481056998; called by muse, mutect2, varscan2
- CTDSPL2 | c.358G>A p.V120I | Missense Mutation (SNP) | VAF 35/213 reads (16%) | SIFT tolerated (0.46); PolyPhen benign (0); catalogued as rs945236392; called by muse, mutect2, varscan2
- CTH | c.1052+1G>A p.X351_splice | Splice Site (SNP) | VAF 47/227 reads (21%) | catalogued as rs570239863, COSV61008491; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CTNNA3 | c.2204C>T p.A735V | Missense Mutation (SNP) | VAF 29/188 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); catalogued as rs1299153203, COSV101041512; called by muse, varscan2
- CTNND1 | c.2233G>T p.E745* (on ENST00000399050 / NM_001085458.2; = p.E739* on NM_001331.3) | Nonsense Mutation (SNP) | VAF 14/73 reads (19%) | catalogued as COSV62382083; called by muse, mutect2, varscan2
- CTNS | c.340C>T p.R114C | Missense Mutation (SNP) | VAF 23/118 reads (19%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.513); catalogued as rs373928453, COSV50442375; called by muse, mutect2, varscan2
- CTR9 | c.1481C>T p.A494V | Missense Mutation (SNP) | VAF 26/116 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.084); catalogued as COSV63728161; called by muse, mutect2, varscan2
- CTSL | c.119A>G p.Y40C | Missense Mutation (SNP) | VAF 57/351 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs200642380; called by muse, mutect2, varscan2
- CTSS | c.142C>T p.R48* | Nonsense Mutation (SNP) | VAF 33/146 reads (23%) | catalogued as rs374721270; called by muse, mutect2, varscan2
- CTSV | c.49G>A p.A17T | Missense Mutation (SNP) | VAF 61/344 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0.337); catalogued as rs757379479, COSV52344154; called by muse, mutect2, varscan2
- CTSW | c.746-1G>T p.X249_splice | Splice Site (SNP) | VAF 25/135 reads (19%) | catalogued as COSV57173421; called by muse, mutect2, varscan2
- CTTN | c.1072G>A p.A358T | Missense Mutation (SNP) | VAF 27/147 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.221); catalogued as rs1260435071, COSV57230213; called by muse, mutect2, varscan2
- CTU2 | c.1413G>T p.K471N | Missense Mutation (SNP) | VAF 12/64 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.651); catalogued as COSV56343464; called by muse, mutect2, varscan2
- CUBN | c.9689C>T p.A3230V | Missense Mutation (SNP) | VAF 30/148 reads (20%) | SIFT tolerated (0.47); PolyPhen possibly damaging (0.71); catalogued as rs139511152; called by muse, varscan2
- CUL7 | c.4945C>T p.P1649S | Missense Mutation (SNP) | VAF 16/64 reads (25%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.685); catalogued as rs1433590023; called by muse, mutect2, varscan2
- CUL9 | c.7051G>A p.V2351M | Missense Mutation (SNP) | VAF 12/81 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1458331166, COSV52736350; called by muse, mutect2, varscan2
- CUX1 | c.622C>T p.R208* (on ENST00000292535 / NM_181552.4; = p.R219* on NM_001913.5) | Nonsense Mutation (SNP) | VAF 82/405 reads (20%) | catalogued as rs782288993, COSV52891789; called by muse, mutect2, varscan2
- CUX1 | c.2993C>T p.P998L | Missense Mutation (SNP) | VAF 13/40 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52910007; called by muse, mutect2, varscan2
- CUX2 | c.4235C>A p.P1412H | Missense Mutation (SNP) | VAF 10/75 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.972); catalogued as COSV55626852; called by muse, varscan2
- CWC25 | c.164G>A p.R55H | Missense Mutation (SNP) | VAF 41/206 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as rs772757218; called by muse, mutect2, varscan2
- CXCL16 | c.154G>A p.V52I | Missense Mutation (SNP) | VAF 15/107 reads (14%) | SIFT tolerated (0.2); PolyPhen benign (0.015); catalogued as rs371670800; called by muse, mutect2, varscan2
- CXCR5 | c.976G>A p.G326S | Missense Mutation (SNP) | VAF 12/61 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs868477374, COSV52682780; called by muse, mutect2, varscan2
- CXorf21 | c.552C>A p.Y184* | Nonsense Mutation (SNP) | VAF 25/113 reads (22%) | catalogued as COSV100973323; called by muse, mutect2, varscan2
- CXorf58 | c.301A>G p.I101V | Missense Mutation (SNP) | VAF 65/288 reads (23%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV101003050; called by muse, mutect2, varscan2
- CYB561 | c.154G>A p.A52T | Missense Mutation (SNP) | VAF 27/95 reads (28%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as COSV62539966; called by muse, mutect2, varscan2
- CYBB | c.677G>A p.R226Q | Missense Mutation (SNP) | VAF 17/83 reads (20%) | SIFT tolerated (0.48); PolyPhen benign (0.003); catalogued as rs782654718, COSV66085896; called by muse, mutect2, varscan2
- CYBB | c.1710C>A p.F570L | Missense Mutation (SNP) | VAF 6/58 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV101059760; called by muse, varscan2
- CYFIP1 | c.3625C>T p.R1209C | Missense Mutation (SNP) | VAF 17/99 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs371607573; called by muse, mutect2, varscan2
- CYFIP1 | c.2887C>A p.P963T | Missense Mutation (SNP) | VAF 10/40 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV100488380; called by muse, mutect2, varscan2
- CYFIP2 | c.3208C>T p.R1070W (on ENST00000616178 / NM_001291722.2; = p.R1045W on NM_014376.4) | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.826); catalogued as rs764928113, COSV59031408; called by mutect2, varscan2
- CYP11A1 | c.695G>A p.R232Q | Missense Mutation (SNP) | VAF 16/90 reads (18%) | SIFT tolerated (0.22); PolyPhen benign (0.007); catalogued as rs754009413, COSV51431425; called by muse, mutect2, varscan2
- CYP11B2 | c.890C>T p.A297V | Missense Mutation (SNP) | VAF 44/211 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.584); catalogued as COSV59997687; called by muse, mutect2, varscan2
- CYP1A2 | c.697G>A p.G233R | Missense Mutation (SNP) | VAF 22/121 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs201537008; called by muse, mutect2
- CYP21A2 | c.448C>T p.R150C | Missense Mutation (SNP) | VAF 10/103 reads (10%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.964); catalogued as rs577450124, CM110264; called by muse, mutect2
- CYP2B6 | c.928G>A p.G310S | Missense Mutation (SNP) | VAF 15/68 reads (22%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.649); catalogued as rs1399326269, COSV57842829; called by muse, mutect2, varscan2
- CYP2C19 | c.890C>A p.A297D | Missense Mutation (SNP) | VAF 59/300 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV64907681; called by muse, mutect2, varscan2
- CYP2U1 | c.680C>A p.A227D | Missense Mutation (SNP) | VAF 26/185 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV60548108; called by muse, mutect2, varscan2
- CYP39A1 | c.865G>A p.V289I | Missense Mutation (SNP) | VAF 25/167 reads (15%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as rs138760821; called by muse, mutect2, varscan2
- CYP4F22 | c.1379G>A p.R460H | Missense Mutation (SNP) | VAF 27/189 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV54111856; called by muse, mutect2, varscan2
- CYP4Z1 | c.1350G>A p.R450= | Splice Region (SNP) | VAF 15/47 reads (32%) | catalogued as rs1229976684, COSV100497449; called by muse, mutect2, varscan2
- CYTH3 | c.796G>A p.D266N | Missense Mutation (SNP) | VAF 54/261 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.494); catalogued as rs1181253011; called by muse, mutect2, varscan2
- D2HGDH | c.387G>T p.Q129H | Missense Mutation (SNP) | VAF 9/51 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58319416; called by muse, mutect2, varscan2
- DAAM2 | c.2257G>A p.D753N | Missense Mutation (SNP) | VAF 13/71 reads (18%) | SIFT tolerated (0.75); PolyPhen benign (0.079); catalogued as COSV51329018; called by muse, mutect2, varscan2
- DAB2 | c.1877C>A p.A626D | Missense Mutation (SNP) | VAF 15/75 reads (20%) | SIFT tolerated (0.1); PolyPhen benign (0.021); catalogued as rs775251043, COSV57913038; called by muse, mutect2, varscan2
- DAGLA | c.1661G>A p.R554Q | Missense Mutation (SNP) | VAF 10/62 reads (16%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.953); catalogued as rs1221142341; called by muse, mutect2, varscan2
- DAP3 | c.81G>T p.Q27H | Missense Mutation (SNP) | VAF 20/119 reads (17%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.45); catalogued as COSV100546523; called by muse, mutect2, varscan2
- DAPP1 | c.617G>A p.R206Q | Missense Mutation (SNP) | VAF 27/149 reads (18%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.613); catalogued as rs1020531964, COSV56452055; called by muse, mutect2, varscan2
10,345 further variants in this file (7,498 protein-altering or splice-affecting, 2,628 silent, 219 other) are not listed here.
